Somatic mutation profile of tumor specimen TCGA-FR-A726-01A (aliquot TCGA-FR-A726-01A-11D-A32N-08) from TCGA case TCGA-FR-A726, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Lentigo maligna melanoma; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIC; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen TCGA-FR-A726-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b5fb4b84-e4a4-4800-98e6-fa4b375e2c27.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FR-A726-10A (Blood Derived Normal), aliquot TCGA-FR-A726-10A-01D-A32N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1dd2eb4a-a2e1-4137-a586-0a9121cc5e3d

The open-access MAF lists 8,473 somatic variants for this specimen: 5,456 protein-altering or splice-affecting, 2,798 silent, 219 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4,968, Silent 2,798, Nonsense Mutation 307, Intron 92, Splice Region 79, RNA 70, Splice Site 70, 3'UTR 23, Translation Start Site 18, 3'Flank 15, 5'UTR 11, Frame Shift Del 9.

Variants (750 of 8,473; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCG5 | c.1222C>T p.R408* | Nonsense Mutation (SNP) | VAF 31/123 reads (25%) | catalogued as rs119479065, CM010003, COSV99575725; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADAR | c.1420C>T p.R474* | Nonsense Mutation (SNP) | VAF 90/164 reads (55%) | catalogued as rs121912421, CM032173, COSV52715378; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ARID2 | c.890C>T p.S297F | Missense Mutation (SNP) | VAF 40/146 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57595738; called by muse, mutect2, varscan2
- CDK5RAP2 | c.4207C>T p.R1403* | Nonsense Mutation (SNP) | VAF 47/143 reads (33%) | catalogued as rs754282058, COSV62578190; ClinVar: pathogenic; called by muse, mutect2, varscan2
- COL3A1 | c.3041G>A p.G1014E | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912916, CM920209, COSV58581416, COSV58592685; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DMD | c.10141C>T p.R3381* | Nonsense Mutation (SNP) | VAF 43/74 reads (58%) | catalogued as rs104894790, CM930196, COSV58930264; ClinVar: pathogenic; called by muse, mutect2, varscan2
- EDAR | c.1024+1G>A p.X342_splice | Splice Site (SNP) | VAF 37/111 reads (33%) | catalogued as rs1553444895, COSV99304465; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- EPHA7 | c.1967G>A p.G656E | Missense Mutation (SNP) | VAF 128/216 reads (59%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV65180770; called by muse, mutect2, varscan2
- ERBB4 | c.1354G>A p.E452K | Missense Mutation (SNP) | VAF 52/154 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.209); catalogued as rs202247795, COSV104368601, COSV53499570; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FLNA | c.3596C>T p.S1199L | Missense Mutation (SNP) | VAF 39/85 reads (46%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); catalogued as rs28935473, CM030673, COSV61040824; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GJA8 | c.827C>T p.S276F | Missense Mutation (SNP) | VAF 70/169 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.055); catalogued as rs45619342, CM081297, COSV53790822; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GLDC | c.2182G>A p.G728R | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs386833542, CM061034, COSV58676669; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KMT2A | c.3451C>T p.R1151* | Nonsense Mutation (SNP) | VAF 104/207 reads (50%) | catalogued as rs868985556, COSV63289633; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MYO18B | c.3052C>T p.P1018S | Missense Mutation (SNP) | VAF 51/160 reads (32%) | hotspot (GDC flag); SIFT tolerated (0.67); PolyPhen benign (0.344); catalogued as COSV100123667, COSV59127388; called by muse, mutect2, varscan2
- RAC1 | c.85C>T p.P29S | Missense Mutation (SNP) | VAF 45/163 reads (28%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.713); catalogued as rs1057519874, COSV61821563, COSV61823187; ClinVar: not provided / likely pathogenic; called by muse, mutect2, varscan2
- SCN5A | c.1604G>A p.R535Q | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.833); catalogued as rs199473121, CM097640, COSV61132438; ClinVar: pathogenic / uncertain significance / not provided; called by mutect2, varscan2
- TTN | c.53272C>T p.R17758* (on ENST00000591111; = p.R10334* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 35/85 reads (41%) | catalogued as rs768073446, COSV100635497; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- A1CF | c.829G>A p.E277K | Missense Mutation (SNP) | VAF 44/110 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.206); catalogued as COSV99258299; called by muse, mutect2, varscan2
- A1CF | c.193C>T p.R65* | Nonsense Mutation (SNP) | VAF 47/210 reads (22%) | catalogued as rs1332342549, COSV50996772, COSV51031701; called by muse, varscan2
- A1CF | c.161G>A p.R54K | Missense Mutation (SNP) | VAF 68/158 reads (43%) | SIFT tolerated (0.19); PolyPhen benign (0.018); catalogued as rs763882781, COSV99258317; called by muse, varscan2
- A2M | c.550G>A p.E184K | Missense Mutation (SNP) | VAF 76/210 reads (36%) | SIFT tolerated (0.38); PolyPhen benign (0.078); catalogued as COSV59383647; called by muse, mutect2, varscan2
- A2M | c.439C>T p.R147C | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs778604418, COSV59383298; called by muse, mutect2, varscan2
- A2ML1 | c.802C>T p.R268* | Nonsense Mutation (SNP) | VAF 42/111 reads (38%) | catalogued as rs759740387, COSV55290147; called by muse, mutect2, varscan2
- A4GALT | c.560G>A p.G187D | Missense Mutation (SNP) | VAF 50/117 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28940572, CM004785, COSV99966825; ClinVar: affects; called by muse, mutect2, varscan2
- AADACL3 | c.1204C>T p.Q402* | Nonsense Mutation (SNP) | VAF 28/93 reads (30%) | catalogued as COSV100206944; called by muse, varscan2
- AAK1 | c.1825C>T p.P609S | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.32); PolyPhen benign (0.14); catalogued as COSV68646351; called by muse, mutect2
- AASDHPPT | c.719T>C p.F240S | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.4); PolyPhen benign (0.39); catalogued as COSV99593478; called by muse, mutect2, varscan2
- ABAT | c.1322C>T p.S441F | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs1254844336, COSV99191063; called by muse, mutect2, varscan2
- ABCA1 | c.4424C>T p.P1475L | Missense Mutation (SNP) | VAF 14/160 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101037786; called by muse, mutect2
- ABCA12 | c.3112G>A p.G1038R (on ENST00000272895 / NM_173076.3; = p.G720R on NM_015657.3) | Missense Mutation (SNP) | VAF 46/176 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99792625; called by muse, mutect2, varscan2
- ABCA13 | c.14635T>A p.L4879I | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV101291465; called by muse, mutect2, varscan2
- ABCA2 | c.680C>T p.P227L (on ENST00000614293; = p.P197L on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); catalogued as rs574467529, COSV55797149; called by muse, varscan2
- ABCA2 | c.679C>T p.P227S (on ENST00000614293; = p.P197S on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as rs778313929, COSV99688644; called by muse, varscan2
- ABCA3 | c.4963C>T p.R1655C | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs764785563, COSV57053091; called by muse, mutect2, varscan2
- ABCA3 | c.3455C>T p.S1152F | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.035); catalogued as COSV100069235, COSV57048836; called by muse, mutect2, varscan2
- ABCA3 | c.251C>T p.P84L | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV100069238; called by muse, mutect2, varscan2
- ABCA4 | c.5372C>T p.A1791V | Missense Mutation (SNP) | VAF 74/269 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100933339; called by muse, mutect2, varscan2
- ABCA4 | c.3743G>A p.R1248K | Missense Mutation (SNP) | VAF 58/199 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.018); catalogued as rs909796557, COSV100933108, COSV100933340; called by muse, mutect2, varscan2
- ABCA5 | c.1061C>T p.S354L | Missense Mutation (SNP) | VAF 33/114 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as rs892454700, COSV101201271; called by muse, mutect2, varscan2
- ABCA8 | c.2170G>A p.D724N | Missense Mutation (SNP) | VAF 31/178 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.078); catalogued as rs866649283, COSV52194270; called by muse, mutect2, varscan2
- ABCA8 | c.1067C>T p.S356F | Missense Mutation (SNP) | VAF 29/112 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.139); catalogued as rs982559760, COSV99287205; called by muse, mutect2, varscan2
- ABCA9 | c.2099C>T p.S700F | Missense Mutation (SNP) | VAF 157/597 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60622637; called by muse, mutect2, varscan2
- ABCB1 | c.2834C>T p.T945I | Missense Mutation (SNP) | VAF 27/175 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as rs766473800, COSV99714821; called by muse, mutect2, varscan2
- ABCB1 | c.2688C>T p.I896= | Splice Region (SNP) | VAF 30/110 reads (27%) | catalogued as rs532094830, COSV99714822; called by muse, mutect2, varscan2
- ABCB1 | c.844G>A p.E282K | Missense Mutation (SNP) | VAF 54/198 reads (27%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.998); catalogued as COSV99714827; called by muse, mutect2, varscan2
- ABCB11 | c.3278C>T p.S1093L | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as rs1030004521, COSV99793428; called by muse, mutect2, varscan2
- ABCB11 | c.2694G>A p.W898* | Nonsense Mutation (SNP) | VAF 45/131 reads (34%) | catalogued as COSV99793432; called by muse, mutect2, varscan2
- ABCB4 | c.3448G>A p.E1150K (on ENST00000265723 / NM_018849.3; = p.E1143K on NM_000443.4) | Missense Mutation (SNP) | VAF 88/376 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.619); catalogued as COSV99709492; called by muse, varscan2
- ABCB4 | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 56/207 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.084); catalogued as COSV99711512; called by muse, mutect2, varscan2
- ABCB4 | c.313C>T p.P105S | Missense Mutation (SNP) | VAF 43/122 reads (35%) | SIFT tolerated (0.69); PolyPhen benign (0.021); catalogued as COSV99711518; called by muse, mutect2, varscan2
- ABCC11 | c.1428T>G p.F476L | Missense Mutation (SNP) | VAF 18/156 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100751251; called by muse, mutect2, varscan2
- ABCC12 | c.1529G>A p.G510E | Missense Mutation (SNP) | VAF 16/174 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100253423; called by muse, mutect2
- ABCC3 | c.3349C>T p.P1117S | Missense Mutation (SNP) | VAF 46/146 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs140501798; called by muse, mutect2, varscan2
- ABCC4 | c.2944G>A p.A982T | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.062); catalogued as COSV100972896; called by muse, mutect2, varscan2
- ABCC4 | c.1353G>A p.K451= | Splice Region (SNP) | VAF 46/104 reads (44%) | catalogued as COSV100972897; called by muse, mutect2, varscan2
- ABCC4 | c.1159C>T p.Q387* | Nonsense Mutation (SNP) | VAF 42/84 reads (50%) | catalogued as COSV65313409; called by muse, mutect2, varscan2
- ABCC6 | c.1120C>T p.L374F | Missense Mutation (SNP) | VAF 68/175 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.632); catalogued as COSV99229895; called by muse, varscan2
- ABCD4 | c.97C>T p.P33S | Missense Mutation (SNP) | VAF 40/97 reads (41%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.71); catalogued as COSV100083950; called by muse, mutect2, varscan2
- ABCF3 | c.692C>T p.P231L | Missense Mutation (SNP) | VAF 67/190 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV53047664, COSV99491074; called by muse, mutect2, varscan2
- ABCG1 | c.885T>A p.C295* | Nonsense Mutation (SNP) | VAF 113/398 reads (28%) | catalogued as COSV100494569; called by muse, mutect2, varscan2
- ABCG1 | c.1033C>T p.R345W | Missense Mutation (SNP) | VAF 103/376 reads (27%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs751587938, COSV59204556, COSV59207097; called by muse, mutect2, varscan2
- ABCG2 | c.535G>A p.G179R | Missense Mutation (SNP) | VAF 37/94 reads (39%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); catalogued as rs1185675198, COSV99420465; called by muse, mutect2, varscan2
- ABHD12 | c.889T>A p.F297I | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV100195132; called by muse, mutect2, varscan2
- ABI3 | c.1057G>A p.G353R | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.879); catalogued as COSV99865921; called by muse, mutect2
- ABI3BP | c.1619C>T p.S540L | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.11); catalogued as COSV99428953; called by muse, mutect2, varscan2
- ABLIM2 | c.1037G>A p.S346N | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as COSV56414189; called by muse, mutect2, varscan2
- ABLIM2 | c.404C>T p.S135F | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.081); catalogued as rs778351418, COSV99590842; called by muse, varscan2
- ABRA | c.872A>G p.E291G | Missense Mutation (SNP) | VAF 45/104 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100357688; called by muse, mutect2, varscan2
- ABRA | c.446G>A p.R149K | Missense Mutation (SNP) | VAF 111/314 reads (35%) | SIFT tolerated (0.85); PolyPhen benign (0.001); catalogued as COSV100357689; called by muse, mutect2, varscan2
- ABT1 | c.545C>T p.T182I | Missense Mutation (SNP) | VAF 43/147 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); catalogued as rs1360394619, COSV99223402; called by muse, mutect2, varscan2
- AC004922.1 | c.79C>T p.P27S | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.87); catalogued as COSV99501359, COSV99501455; called by muse, mutect2, varscan2
- AC100868.1 | c.2039C>T p.P680L | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.03); catalogued as rs761441732, COSV51845748; called by muse, mutect2, varscan2
- AC100868.1 | c.979G>A p.D327N | Missense Mutation (SNP) | VAF 91/260 reads (35%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.987); catalogued as COSV51849811, COSV51851501; called by muse, mutect2, varscan2
- ACACB | c.5801G>A p.R1934Q | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1049370630, COSV58127596; called by muse, mutect2, varscan2
- ACAD9 | c.169C>T p.P57S | Missense Mutation (SNP) | VAF 53/128 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58307522; called by muse, mutect2, varscan2
- ACAN | c.6734G>A p.G2245E | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.3); PolyPhen probably damaging (1); catalogued as COSV61371834; called by muse, mutect2, varscan2
- ACCS | c.767C>T p.P256L | Missense Mutation (SNP) | VAF 33/85 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV55458291; called by muse, mutect2, varscan2
- ACCSL | c.1495G>A p.E499K | Missense Mutation (SNP) | VAF 67/233 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.833); catalogued as COSV101122337; called by muse, mutect2, varscan2
- ACE | c.3043C>T p.H1015Y | Missense Mutation (SNP) | VAF 45/166 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99327934; called by muse, mutect2, varscan2
- ACER1 | c.706G>A p.E236K | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV100034163; called by muse, mutect2, varscan2
- ACKR1 | c.577G>A p.G193R | Missense Mutation (SNP) | VAF 42/76 reads (55%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100929712; called by muse, mutect2, varscan2
- ACKR2 | c.547G>T p.V183L | Missense Mutation (SNP) | VAF 68/212 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.056); catalogued as COSV99825836; called by muse, mutect2, varscan2
- ACMSD | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 35/83 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.125); catalogued as COSV51606597, COSV51607729; called by muse, mutect2, varscan2
- ACMSD | c.70G>A p.G24R | Missense Mutation (SNP) | VAF 49/163 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.375); catalogued as rs370698092, COSV51605614; called by muse, mutect2, varscan2
- ACMSD | c.175C>T p.R59C | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs267598885, COSV51606002, COSV51609903; called by muse, mutect2, varscan2
- ACMSD | c.326G>A p.R109K | Missense Mutation (SNP) | VAF 50/126 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99299566; called by muse, varscan2
- ACOT1 | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 112/163 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100233469; called by muse, mutect2, varscan2
- ACOT11 | c.129C>G p.N43K | Missense Mutation (SNP) | VAF 31/106 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.159); catalogued as COSV100650821; called by muse, mutect2, varscan2
- ACOT12 | c.709G>A p.G237R | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100297248; called by muse, mutect2
- ACOX2 | c.782G>C p.R261P | Missense Mutation (SNP) | VAF 51/130 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100250334; called by muse, mutect2, varscan2
- ACOXL | c.643G>A p.G215R | Missense Mutation (SNP) | VAF 57/203 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.913); catalogued as COSV100490691, COSV100490744; called by muse, mutect2, varscan2
- ACOXL | c.644G>A p.G215E | Missense Mutation (SNP) | VAF 55/200 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100490746; called by muse, mutect2, varscan2
- ACP3 | c.439C>T p.P147S | Missense Mutation (SNP) | VAF 36/83 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.07); catalogued as COSV100313651; called by muse, mutect2, varscan2
- ACRBP | c.1208C>T p.P403L | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.018); catalogued as COSV57524667; called by muse, mutect2, varscan2
- ACSBG1 | c.518C>T p.S173L | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.097); catalogued as rs982351265, COSV99357906; called by muse, mutect2, varscan2
- ACSBG2 | c.962C>T p.P321L | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99397729; called by muse, varscan2
- ACSL4 | c.1301G>A p.G434E (on ENST00000340800 / NM_022977.2; = p.G393E on NM_004458.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 52/69 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100539176; called by muse, mutect2, varscan2
- ACSM2A | c.382C>T p.R128* (on ENST00000219054; = p.R49* on NM_001308169.2) | Nonsense Mutation (SNP) | VAF 10/60 reads (17%) | catalogued as rs748565082, COSV54589440; called by muse, mutect2
- ACSM2B | c.1118C>T p.S373F | Missense Mutation (SNP) | VAF 34/169 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as rs1391640961, COSV100313273; called by muse, mutect2, varscan2
- ACSM2B | c.243G>A p.W81* | Nonsense Mutation (SNP) | VAF 14/50 reads (28%) | catalogued as COSV100313274; called by muse, mutect2, varscan2
- ACSM3 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 67/183 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.168); catalogued as rs374112838, COSV55503003; called by muse, mutect2, varscan2
- ACSM4 | c.765G>A p.R255= | Splice Region (SNP) | VAF 15/54 reads (28%) | catalogued as COSV101257463; called by muse, mutect2, varscan2
- ACSS3 | c.140G>A p.G47E | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV54100264, COSV99699640; called by muse, mutect2
- ACSS3 | c.1732C>T p.H578Y | Missense Mutation (SNP) | VAF 77/271 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.266); catalogued as COSV99699644; called by muse, mutect2, varscan2
- ACTA2 | c.646G>A p.E216K | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99827274; called by muse, mutect2, varscan2
- ACTL7B | c.580G>A p.G194R | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101012480, COSV101012601; called by muse, mutect2, varscan2
- ACTL7B | c.425C>T p.P142L | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.137); catalogued as rs909538683, COSV65927126; called by muse, mutect2, varscan2
- ACTN2 | c.850G>A p.E284K | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV100857110, COSV63977537; called by muse, varscan2
- ACTN3 | c.1253C>T p.S418F | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.496); catalogued as COSV101557919; called by muse, mutect2, varscan2
- ACTRT1 | c.949G>A p.E317K | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV64419311; called by muse, mutect2
- ACTRT1 | c.349G>A p.E117K | Missense Mutation (SNP) | VAF 191/278 reads (69%) | SIFT tolerated (0.35); PolyPhen benign (0.058); catalogued as COSV64419395; called by muse, mutect2, varscan2
- ACTRT2 | c.671C>T p.A224V | Missense Mutation (SNP) | VAF 54/144 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.168); catalogued as rs1243739357, COSV101007696; called by muse, mutect2, varscan2
- ACVR1B | c.34C>T p.P12S | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.87); PolyPhen benign (0.009); catalogued as rs1311413571, COSV99232192; called by muse, mutect2
- ACVR1C | c.1429C>T p.R477C | Missense Mutation (SNP) | VAF 41/148 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1376322387, COSV54643947; called by muse, mutect2, varscan2
- ADAD1 | c.676G>A p.E226K | Missense Mutation (SNP) | VAF 37/112 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.092); catalogued as COSV99636470; called by muse, mutect2, varscan2
- ADAM12 | c.1345C>T p.R449C | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as rs763234587, COSV64110435, COSV64111020; called by muse, mutect2, varscan2
- ADAM18 | c.287G>A p.G96E | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55852001; called by muse, mutect2, varscan2
- ADAM19 | c.592C>T p.P198S | Missense Mutation (SNP) | VAF 53/189 reads (28%) | SIFT tolerated (0.54); PolyPhen benign (0.007); catalogued as COSV99978816; called by muse, mutect2, varscan2
- ADAM20 | c.1201C>T p.P401S | Missense Mutation (SNP) | VAF 50/161 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.04); catalogued as COSV99833651; called by muse, mutect2, varscan2
- ADAM22 | c.1209G>A p.M403I | Missense Mutation (SNP) | VAF 35/164 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99715583, COSV99718720; called by muse, mutect2, varscan2
- ADAM22 | c.1486-1G>A p.X496_splice | Splice Site (SNP) | VAF 11/42 reads (26%) | catalogued as COSV99718722; called by muse, mutect2, varscan2
- ADAM28 | c.797C>T p.T266I | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); catalogued as COSV99739281; called by muse, mutect2, varscan2
- ADAM29 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 23/97 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0.214); catalogued as rs1450911178, COSV63667370; called by muse, mutect2, varscan2
- ADAM29 | c.701C>T p.S234F | Missense Mutation (SNP) | VAF 57/154 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.395); catalogued as rs866380131, COSV63667068; called by muse, varscan2
- ADAM29 | c.2107C>T p.P703S | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as COSV100822307; called by muse, mutect2, varscan2
- ADAM30 | c.553C>T p.P185S | Missense Mutation (SNP) | VAF 49/123 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV101024013; called by muse, mutect2, varscan2
- ADAMDEC1 | c.679G>A p.D227N | Missense Mutation (SNP) | VAF 36/71 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99836364; called by muse, mutect2, varscan2
- ADAMDEC1 | c.949C>T p.R317* | Nonsense Mutation (SNP) | VAF 14/132 reads (11%) | catalogued as rs1434377951, COSV56476584; called by muse, varscan2
- ADAMTS12 | c.3281C>T p.S1094F | Missense Mutation (SNP) | VAF 42/116 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.312); catalogued as COSV100711797; called by muse, mutect2, varscan2
- ADAMTS14 | c.517G>A p.G173R | Missense Mutation (SNP) | VAF 40/112 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1047684991, COSV64599846; called by muse, mutect2, varscan2
- ADAMTS15 | c.1441C>T p.Q481* | Nonsense Mutation (SNP) | VAF 28/86 reads (33%) | catalogued as COSV100143900; called by muse, mutect2, varscan2
- ADAMTS15 | c.2350C>T p.L784F | Missense Mutation (SNP) | VAF 68/128 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV100143902, COSV54504066; called by muse, mutect2, varscan2
- ADAMTS18 | c.592C>T p.H198Y | Missense Mutation (SNP) | VAF 41/86 reads (48%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.968); catalogued as rs1054421685, COSV99274665; called by muse, mutect2, varscan2
- ADAMTS19 | c.1580G>A p.W527* | Nonsense Mutation (SNP) | VAF 84/278 reads (30%) | catalogued as COSV99184127; called by muse, mutect2, varscan2
- ADAMTS2 | c.1310C>T p.P437L | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1368938062, COSV99206546; called by muse, mutect2, varscan2
- ADAMTS20 | c.3751C>T p.R1251C | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs777466280, COSV67131235, COSV67139700; called by muse, mutect2, varscan2
- ADAMTS20 | c.3055G>A p.E1019K | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.841); catalogued as COSV67128809, COSV67131706; called by muse, mutect2, varscan2
- ADAMTS20 | c.2506T>A p.S836T | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT tolerated (0.3); PolyPhen benign (0.098); catalogued as COSV101166430; called by muse, mutect2, varscan2
- ADAMTS20 | c.1853G>A p.R618Q | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752301075, COSV67126374, COSV67136307; called by muse, mutect2, varscan2
- ADAMTS3 | c.513G>A p.M171I | Missense Mutation (SNP) | VAF 32/109 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.089); catalogued as COSV54386835; called by muse, mutect2, varscan2
- ADAMTS5 | c.734C>T p.S245L | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.38); PolyPhen benign (0.022); catalogued as rs1452439093, COSV99538524; called by muse, mutect2
- ADAMTS6 | c.2904G>A p.W968* | Nonsense Mutation (SNP) | VAF 58/160 reads (36%) | catalogued as COSV100068699; called by muse, varscan2
- ADAMTS6 | c.2854G>A p.E952K | Missense Mutation (SNP) | VAF 66/242 reads (27%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.899); catalogued as COSV100068703; called by muse, varscan2
- ADAMTS7 | c.995C>T p.P332L | Missense Mutation (SNP) | VAF 52/165 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV66310007; called by muse, mutect2, varscan2
- ADAMTS9 | c.832G>A p.E278K | Missense Mutation (SNP) | VAF 132/338 reads (39%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs1559815367, COSV99900432; called by muse, mutect2, varscan2
- ADAMTS9 | c.635C>T p.P212L | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs111443323, COSV99900435; called by muse, mutect2, varscan2
- ADAMTSL1 | c.692C>T p.T231I | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs748456601, COSV99445462; called by muse, mutect2, varscan2
- ADAMTSL3 | c.1199C>T p.P400L | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs1262239154, COSV99721824; called by muse, mutect2, varscan2
- ADAMTSL4 | c.2257G>A p.E753K | Missense Mutation (SNP) | VAF 136/262 reads (52%) | SIFT tolerated (0.08); PolyPhen benign (0.338); catalogued as COSV55003037; called by muse, mutect2, varscan2
- ADAMTSL5 | c.85G>A p.G29R | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); catalogued as COSV100389280; called by muse, mutect2, varscan2
- ADARB2 | c.1385G>A p.R462Q | Missense Mutation (SNP) | VAF 55/154 reads (36%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as rs139936295; called by muse, mutect2, varscan2
- ADCK5 | c.193C>T p.R65C | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.16); PolyPhen benign (0.033); catalogued as rs782782811, COSV100450557; called by muse, mutect2, varscan2
- ADCY1 | c.2087C>T p.P696L | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as rs564193881, COSV99813123; called by muse, mutect2, varscan2
- ADCY10 | c.2329G>A p.E777K | Missense Mutation (SNP) | VAF 45/186 reads (24%) | SIFT tolerated (0.53); PolyPhen benign (0.039); catalogued as rs553997453, COSV100897146; called by muse, mutect2, varscan2
- ADCY7 | c.1368+1G>A p.X456_splice | Splice Site (SNP) | VAF 6/14 reads (43%) | catalogued as COSV99576478; called by muse, mutect2
- ADCY8 | c.2200C>T p.P734S | Missense Mutation (SNP) | VAF 40/100 reads (40%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.718); catalogued as rs866330045, COSV53912362; called by muse, mutect2, varscan2
- ADCY8 | c.1360C>T p.H454Y | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as rs754714304, COSV53920422; called by muse, mutect2, varscan2
- ADCY8 | c.1225C>T p.R409C | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as rs1335694203, COSV53903757, COSV99654082; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 35/80 reads (44%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.025); catalogued as rs1307857192, COSV100416360, COSV58441241; called by muse, mutect2, varscan2
- ADD2 | c.2136_2137insG p.S713Vfs*44 | Frame Shift Ins (INS) | VAF 82/346 reads (24%) | catalogued as COSV100036720; called by pindel, varscan2
- ADD2 | c.1589G>A p.S530N | Missense Mutation (SNP) | VAF 40/114 reads (35%) | SIFT tolerated (0.46); PolyPhen benign (0.028); catalogued as COSV100036722; called by muse, varscan2
- ADD2 | c.922C>T p.H308Y | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.837); catalogued as COSV100036726; called by muse, mutect2, varscan2
- ADD2 | c.56C>T p.P19L | Missense Mutation (SNP) | VAF 65/180 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.012); catalogued as COSV100036730; called by muse, varscan2
- ADGRB2 | c.2086C>T p.R696C | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.532); catalogued as rs267598547, COSV57073539; called by muse, mutect2, varscan2
- ADGRB3 | c.1003G>A p.V335I | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.52); PolyPhen benign (0.062); catalogued as rs779099320, COSV101002100; called by mutect2, varscan2
- ADGRB3 | c.2915G>A p.G972E | Missense Mutation (SNP) | VAF 13/156 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53235597; called by muse, mutect2
- ADGRB3 | c.3502C>T p.P1168S | Missense Mutation (SNP) | VAF 42/150 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.053); catalogued as COSV104381236, COSV53261573, COSV99487284; called by muse, varscan2
- ADGRB3 | c.3518C>T p.S1173F | Missense Mutation (SNP) | VAF 96/152 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.523); catalogued as rs868010056, COSV53240104, COSV99484539; called by muse, varscan2
- ADGRD1 | c.1250G>A p.R417K | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT tolerated (0.54); PolyPhen benign (0.006); catalogued as COSV99897528; called by muse, mutect2, varscan2
- ADGRD1 | c.2069C>T p.S690L | Missense Mutation (SNP) | VAF 65/223 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as COSV99897530; called by muse, varscan2
- ADGRE1 | c.802+2T>G p.X268_splice | Splice Site (SNP) | VAF 42/120 reads (35%) | catalogued as COSV51683071; called by muse, mutect2, varscan2
- ADGRF1 | c.2524G>A p.D842N | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99347753; called by muse, mutect2, varscan2
- ADGRF1 | c.787G>A p.G263R | Missense Mutation (SNP) | VAF 31/111 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99347756; called by muse, mutect2, varscan2
- ADGRF2 | c.1670C>T p.S557L (on ENST00000296862 / NM_001368115.2; = p.S489L on NM_153839.7) | Missense Mutation (SNP) | VAF 46/153 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.395); catalogued as COSV99732025; called by muse, mutect2, varscan2
- ADGRG4 | c.758C>T p.S253F | Missense Mutation (SNP) | VAF 31/46 reads (67%) | SIFT tolerated (0.09); PolyPhen benign (0.234); catalogued as COSV99797456; called by muse, mutect2, varscan2
- ADGRG4 | c.1402C>T p.P468S | Missense Mutation (SNP) | VAF 44/66 reads (67%) | SIFT deleterious (0.02); PolyPhen benign (0.02); catalogued as COSV99797461; called by muse, mutect2, varscan2
- ADGRG4 | c.3797G>A p.G1266E | Missense Mutation (SNP) | VAF 62/81 reads (77%) | SIFT tolerated (0.19); PolyPhen benign (0.024); catalogued as rs748033473, COSV54955639; called by muse, mutect2, varscan2
- ADGRG4 | c.5855C>T p.S1952F | Missense Mutation (SNP) | VAF 67/110 reads (61%) | SIFT deleterious (0.04); PolyPhen benign (0.024); catalogued as COSV99797469; called by muse, mutect2, varscan2
- ADGRG7 | c.597+1G>A p.X199_splice | Splice Site (SNP) | VAF 25/79 reads (32%) | catalogued as rs1342923816, COSV99841694; called by muse, mutect2, varscan2
- ADGRG7 | c.1024G>A p.D342N | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56299253; called by muse, mutect2, varscan2
- ADGRL2 | c.238G>A p.E80K | Missense Mutation (SNP) | VAF 53/141 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99592092; called by muse, mutect2, varscan2
- ADGRL2 | c.632G>A p.G211E | Missense Mutation (SNP) | VAF 37/112 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54672787; called by muse, mutect2, varscan2
- ADGRL2 | c.1492G>A p.G498R | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99592098; called by muse, mutect2, varscan2
- ADGRL2 | c.3535C>T p.R1179* | Nonsense Mutation (SNP) | VAF 37/115 reads (32%) | catalogued as rs754660598, COSV99592101; called by muse, mutect2, varscan2
- ADGRL4 | c.1823G>T p.S608I | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100876625; called by muse, mutect2, varscan2
- ADGRL4 | c.967G>A p.D323N | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT tolerated (0.53); PolyPhen benign (0.009); catalogued as COSV66061072, COSV66066339; called by muse, mutect2, varscan2
- ADGRL4 | c.443G>A p.R148K | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (0.78); PolyPhen benign (0.003); catalogued as COSV100876627; called by muse, mutect2, varscan2
- ADGRV1 | c.935C>T p.S312F | Missense Mutation (SNP) | VAF 43/109 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); catalogued as COSV101316684; called by muse, mutect2, varscan2
- ADGRV1 | c.1681C>T p.P561S | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1489463964, COSV101316686; called by muse, mutect2, varscan2
- ADGRV1 | c.10888G>A p.G3630R | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV67986485; called by muse, mutect2, varscan2
- ADGRV1 | c.14224G>A p.E4742K | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs372362723, COSV67984217; called by muse, mutect2, varscan2
- ADGRV1 | c.14766G>A p.W4922* | Nonsense Mutation (SNP) | VAF 24/65 reads (37%) | catalogued as COSV101316692; called by muse, mutect2, varscan2
- ADGRV1 | c.18676C>T p.P6226S | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.53); PolyPhen benign (0.015); catalogued as COSV101316693; called by muse, mutect2, varscan2
- ADH1A | c.703G>A p.E235K | Missense Mutation (SNP) | VAF 190/659 reads (29%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.735); catalogued as COSV99266026; called by muse, mutect2, varscan2
- ADH1B | c.769G>A p.E257K | Missense Mutation (SNP) | VAF 170/494 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.787); catalogued as COSV59294987; called by muse, mutect2
- ADH1B | c.151G>A p.D51N | Missense Mutation (SNP) | VAF 52/227 reads (23%) | SIFT tolerated (0.36); PolyPhen benign (0.156); catalogued as rs1481323916, COSV100520911; called by muse, varscan2
- ADM2 | c.152G>A p.R51K | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.46); PolyPhen benign (0.011); catalogued as COSV99327177; called by muse, mutect2, varscan2
- ADNP | c.2624C>T p.S875F | Missense Mutation (SNP) | VAF 63/211 reads (30%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); catalogued as COSV100823902; called by muse, mutect2, varscan2
- ADNP2 | c.1258C>T p.P420S | Missense Mutation (SNP) | VAF 57/145 reads (39%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.964); catalogued as COSV100081303; called by muse, mutect2, varscan2
- AEN | c.49C>T p.L17F | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs749170954, COSV100237675; called by muse, mutect2, varscan2
- AFAP1 | c.1529C>T p.S510L | Missense Mutation (SNP) | VAF 43/130 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0.036); catalogued as rs371401645, COSV100632370; called by muse, mutect2, varscan2
- AFAP1L1 | c.1681C>T p.P561S | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.031); catalogued as COSV99696213; called by muse, mutect2, varscan2
- AFAP1L1 | c.1705G>A p.E569K | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as COSV99696214; called by muse, mutect2, varscan2
- AFDN | c.2731G>A p.D911N | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60042096; called by muse, mutect2, varscan2
- AFF1 | c.838C>T p.P280S | Missense Mutation (SNP) | VAF 94/300 reads (31%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); catalogued as COSV100321163; called by muse, mutect2, varscan2
- AFF2 | c.3068T>A p.I1023N | Missense Mutation (SNP) | VAF 148/187 reads (79%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.996); catalogued as COSV99663206; called by muse, mutect2, varscan2
- AGAP3 | c.263C>T p.S88F (on ENST00000622464; = p.S124F on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 74/282 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV100103773, COSV100103971; called by muse, varscan2
- AGAP3 | c.1452G>A p.W484* (on ENST00000622464; = p.W520* on NM_031946.7 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 27/62 reads (44%) | catalogued as rs1563524017, COSV101257505; called by muse, mutect2, varscan2
- AGBL1 | c.685G>T p.E229* | Nonsense Mutation (SNP) | VAF 38/101 reads (38%) | catalogued as COSV101408292; called by muse, mutect2, varscan2
- AGBL1 | c.2080C>T p.H694Y | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); catalogued as COSV66847341; called by muse, mutect2
- AGBL2 | c.1241C>T p.P414L | Missense Mutation (SNP) | VAF 49/152 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as rs780980581, COSV100102256; called by muse, mutect2, varscan2
- AGGF1 | c.680C>T p.S227F | Missense Mutation (SNP) | VAF 39/111 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV57229165; called by muse, varscan2
- AGO1 | c.1640T>G p.V547G | Missense Mutation (SNP) | VAF 16/149 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.013); catalogued as COSV100940954; called by muse, mutect2, varscan2
- AGO4 | c.362C>T p.S121F | Missense Mutation (SNP) | VAF 69/240 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.063); catalogued as COSV100943134; called by muse, mutect2, varscan2
- AGPAT4 | c.1046C>T p.S349F | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as COSV57249632; called by muse, mutect2, varscan2
- AGRN | c.3286C>T p.P1096S | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0.026); catalogued as rs766445747, COSV101038684, COSV65072201; called by muse, varscan2
- AGT | c.457C>A p.H153N | Missense Mutation (SNP) | VAF 16/242 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.071); catalogued as COSV100794510; called by muse, mutect2
- AGT | c.355G>A p.G119S | Missense Mutation (SNP) | VAF 89/218 reads (41%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV100794515; called by muse, mutect2, varscan2
- AGTR1 | c.571C>T p.L191F | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.029); catalogued as rs764933525, COSV100837228; called by muse, mutect2, varscan2
- AGTR1 | c.657G>A p.W219* | Nonsense Mutation (SNP) | VAF 29/88 reads (33%) | catalogued as rs1233443416, COSV62557497, COSV62559219; called by muse, mutect2, varscan2
- AGTR2 | c.414G>A p.M138I | Missense Mutation (SNP) | VAF 143/198 reads (72%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); catalogued as rs1556673740, COSV100903641; called by muse, varscan2
- AGTR2 | c.811C>T p.P271S | Missense Mutation (SNP) | VAF 68/103 reads (66%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100903642; called by muse, mutect2, varscan2
- AHDC1 | c.1444C>T p.P482S | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99899845; called by muse, mutect2, varscan2
- AHNAK2 | c.14111T>G p.F4704C | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as COSV100319310; called by muse, mutect2, varscan2
- AHNAK2 | c.793C>T p.Q265* | Nonsense Mutation (SNP) | VAF 18/50 reads (36%) | catalogued as COSV60908156; called by muse, mutect2, varscan2
- AIRE | c.592G>A p.D198N | Missense Mutation (SNP) | VAF 54/153 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV99381573; called by muse, varscan2
- AIRE | c.1378C>T p.P460S | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.537); catalogued as rs55840791, COSV99381577; called by muse, mutect2, varscan2
- AJAP1 | c.665C>T p.T222I | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.03); catalogued as COSV100982070; called by muse, mutect2, varscan2
- AK5 | c.115G>A p.E39K (on ENST00000354567 / NM_174858.3; = p.E13K on NM_012093.4) | Missense Mutation (SNP) | VAF 45/137 reads (33%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.949); catalogued as COSV100481590; called by muse, mutect2, varscan2
- AKAP11 | c.1016C>T p.P339L | Missense Mutation (SNP) | VAF 34/100 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1566271695, COSV99214466; called by muse, mutect2, varscan2
- AKAP11 | c.1441C>T p.H481Y | Missense Mutation (SNP) | VAF 50/157 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV50296210; called by muse, mutect2, varscan2
- AKAP11 | c.2790A>C p.E930D | Missense Mutation (SNP) | VAF 37/108 reads (34%) | SIFT tolerated (0.53); PolyPhen benign (0.015); catalogued as COSV99214471; called by muse, mutect2, varscan2
- AKAP13 | c.802C>T p.P268S | Missense Mutation (SNP) | VAF 71/203 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as COSV100774887; called by muse, mutect2, varscan2
- AKAP9 | c.9836G>A p.R3279K (on ENST00000359028; = p.R3255K on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/186 reads (20%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV100663366; called by muse, mutect2, varscan2
- AKNA | c.2854G>A p.G952R | Missense Mutation (SNP) | VAF 36/109 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.634); catalogued as COSV99801250; called by muse, mutect2, varscan2
- AKNAD1 | c.1130G>A p.G377E | Missense Mutation (SNP) | VAF 49/170 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100645952; called by muse, mutect2, varscan2
- AKR1A1 | c.635C>T p.P212L | Missense Mutation (SNP) | VAF 33/110 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100698817; called by muse, mutect2, varscan2
- AKR1B10 | c.295G>A p.D99N | Missense Mutation (SNP) | VAF 67/312 reads (21%) | SIFT tolerated (0.39); PolyPhen benign (0.094); catalogued as COSV62055090; called by muse, mutect2, varscan2
- AKR1B10 | c.729A>T p.K243N | Missense Mutation (SNP) | VAF 57/210 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV100610276; called by muse, mutect2, varscan2
- AKR1C4 | c.450C>T p.V150= | Splice Region (SNP) | VAF 38/120 reads (32%) | catalogued as rs782243403, COSV99578577; called by muse, mutect2, varscan2
- AL035461.3 | c.2891C>T p.S964F | Missense Mutation (SNP) | VAF 49/149 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV101125878; called by muse, mutect2, varscan2
- AL049569.3 | c.37C>T p.P13S | Missense Mutation (SNP) | VAF 11/25 reads (44%) | PolyPhen possibly damaging (0.81); catalogued as COSV100454533; called by muse, mutect2, varscan2
- AL121899.2 | c.495G>A p.M165I | Missense Mutation (SNP) | VAF 59/201 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.021); catalogued as rs1313619929, COSV101198716; called by muse, mutect2, varscan2
- AL592490.1 | c.2747G>A p.G916E | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs777669673, COSV101308314; called by muse, mutect2, varscan2
- AL592490.1 | c.2333C>T p.A778V | Missense Mutation (SNP) | VAF 37/69 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV101308315; called by muse, mutect2, varscan2
- AL645922.1 | c.1693C>T p.P565S | Missense Mutation (SNP) | VAF 47/147 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs560218488, COSV100191605; called by muse, mutect2, varscan2
- AL645922.1 | c.2224G>A p.E742K | Missense Mutation (SNP) | VAF 24/516 reads (5%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.991); catalogued as COSV100191450, COSV100191608; called by muse, mutect2
- ALDH1L1 | c.23A>T p.Q8L | Missense Mutation (SNP) | VAF 41/127 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99857687; called by muse, mutect2, varscan2
- ALG10B | c.895C>T p.L299F | Missense Mutation (SNP) | VAF 74/238 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.092); catalogued as rs764755710, COSV100440065; called by muse, mutect2, varscan2
- ALG12 | c.254T>A p.L85H | Missense Mutation (SNP) | VAF 37/149 reads (25%) | PolyPhen probably damaging (0.981); catalogued as COSV100427250; called by muse, mutect2, varscan2
- ALG2 | c.632T>A p.V211D | Missense Mutation (SNP) | VAF 35/105 reads (33%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as COSV99445784; called by muse, mutect2, varscan2
- ALG3 | c.1282C>T p.P428S | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as COSV99891793; called by muse, mutect2, varscan2
- ALK | c.2855G>A p.G952E | Missense Mutation (SNP) | VAF 52/163 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101202835; called by muse, mutect2, varscan2
- ALK | c.886G>A p.E296K | Missense Mutation (SNP) | VAF 62/208 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.993); catalogued as rs56077855, COSV66575550; ClinVar: likely benign; called by muse, varscan2
- ALKBH6 | c.103G>A p.E35K (on ENST00000252984 / NM_001297701.2; = p.E63K on NM_032878.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 65/202 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs760454320, COSV99431361; called by muse, mutect2, varscan2
- ALMS1 | c.2753C>T p.S918F | Missense Mutation (SNP) | VAF 55/187 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.036); catalogued as rs369228801, COSV100044141; called by muse, mutect2, varscan2
- ALOX12 | c.648G>A p.E216= | Splice Region (SNP) | VAF 25/78 reads (32%) | catalogued as COSV99278592; called by muse, mutect2, varscan2
- ALOX12B | c.1528G>A p.E510K | Missense Mutation (SNP) | VAF 31/124 reads (25%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.449); catalogued as COSV100047880; called by muse, mutect2, varscan2
- ALOX12B | c.1100C>T p.P367L | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100047885; called by muse, mutect2, varscan2
- ALOX12B | c.1099C>T p.P367S | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100047887; called by muse, mutect2, varscan2
- ALOXE3 | c.1856C>T p.T619I | Missense Mutation (SNP) | VAF 33/118 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.141); catalogued as COSV100560070; called by muse, mutect2, varscan2
- ALPG | c.1342G>A p.G448R | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.015); catalogued as COSV54967137; called by muse, mutect2, varscan2
- ALPK2 | c.5236G>A p.E1746K | Missense Mutation (SNP) | VAF 58/180 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.404); catalogued as COSV100864934; called by muse, mutect2, varscan2
- ALPK2 | c.4607C>T p.S1536F | Missense Mutation (SNP) | VAF 40/114 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs772550142, COSV100864356, COSV64492813; called by muse, mutect2, varscan2
- ALPK2 | c.2953C>T p.P985S | Missense Mutation (SNP) | VAF 35/133 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.051); catalogued as rs1440266458, COSV64494717; called by muse, mutect2, varscan2
- ALPK2 | c.2057C>T p.T686I | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.503); catalogued as COSV100864935; called by muse, varscan2
- ALPK2 | c.1630G>A p.G544R | Missense Mutation (SNP) | VAF 72/231 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.091); catalogued as COSV100864936, COSV64497269; called by muse, mutect2, varscan2
- ALS2CL | c.1978G>A p.E660K | Missense Mutation (SNP) | VAF 46/106 reads (43%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.994); catalogued as COSV100015389; called by muse, mutect2, varscan2
- ALS2CL | c.1389G>A p.W463* | Nonsense Mutation (SNP) | VAF 94/288 reads (33%) | catalogued as COSV59670754; called by muse, mutect2, varscan2
- ALS2CL | c.1388G>A p.W463* | Nonsense Mutation (SNP) | VAF 93/285 reads (33%) | catalogued as COSV100015391; called by muse, mutect2, varscan2
- ALX4 | c.1007C>T p.A336V | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.044); catalogued as rs1236496444, COSV100241377; called by muse, mutect2, varscan2
- AMBN | c.1168G>A p.E390K | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.697); catalogued as COSV100534544; called by muse, mutect2, varscan2
- AMER3 | c.122C>T p.P41L | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV100367008, COSV99068192; called by muse, mutect2, varscan2
- AMER3 | c.2491G>A p.E831K | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as COSV58470349; called by muse, mutect2, varscan2
- AMFR | c.328C>T p.L110F | Missense Mutation (SNP) | VAF 71/127 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51923085, COSV99316296; called by muse, mutect2, varscan2
- AMIGO2 | c.1394G>A p.R465K | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.581); catalogued as rs1411505965, COSV99873500, COSV99873842; called by muse, mutect2, varscan2
- AMIGO3 | c.1442C>T p.P481L | Missense Mutation (SNP) | VAF 42/97 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV100246792; called by muse, mutect2, varscan2
- AMPD1 | c.341C>T p.T114I | Missense Mutation (SNP) | VAF 31/128 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.266); catalogued as COSV62414949; called by muse, mutect2, varscan2
- AMPD3 | c.805C>T p.P269S (on ENST00000396553 / NM_001025389.2; = p.P278S on NM_000480.3) | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs751512356, COSV101158297; called by muse, mutect2, varscan2
- AMPH | c.1847C>T p.S616F | Missense Mutation (SNP) | VAF 37/112 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV100344093; called by muse, mutect2, varscan2
- AMPH | c.830C>T p.P277L | Missense Mutation (SNP) | VAF 51/176 reads (29%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.654); catalogued as COSV100344094; called by muse, mutect2, varscan2
- ANAPC1 | c.3010C>T p.P1004S | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs1305559066; called by mutect2, varscan2
- ANAPC2 | c.370C>T p.P124S | Missense Mutation (SNP) | VAF 59/192 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.046); catalogued as rs936423625, COSV100119271; called by muse, mutect2, varscan2
- ANGEL1 | c.950T>C p.F317S | Missense Mutation (SNP) | VAF 64/268 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV99200523; called by muse, varscan2
- ANGEL2 | c.55G>A p.G19S | Missense Mutation (SNP) | VAF 52/190 reads (27%) | SIFT tolerated, low confidence (0.29); PolyPhen probably damaging (0.997); catalogued as rs1432652134, COSV100854014; called by muse, mutect2, varscan2
- ANGPT1 | c.1238G>A p.G413E | Missense Mutation (SNP) | VAF 40/114 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs138754767, COSV52431155; called by muse, mutect2, varscan2
- ANGPTL1 | c.504G>A p.M168I | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.017); catalogued as COSV52365375; called by muse, mutect2
- ANGPTL1 | c.343G>A p.E115K | Missense Mutation (SNP) | VAF 80/179 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV52366583; called by muse, mutect2, varscan2
- ANGPTL1 | c.101G>A p.R34K | Missense Mutation (SNP) | VAF 56/109 reads (51%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99328441; called by muse, mutect2, varscan2
- ANGPTL7 | c.619G>A p.E207K | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.3); catalogued as rs376924013; called by muse, mutect2, varscan2
- ANK1 | c.2524G>A p.E842K | Missense Mutation (SNP) | VAF 78/262 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.011); catalogued as COSV99227294; called by muse, mutect2, varscan2
- ANK2 | c.11635C>T p.P3879S | Missense Mutation (SNP) | VAF 16/194 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.27); catalogued as COSV100004785; called by muse, mutect2
- ANK3 | c.12182C>A p.A4061E | Missense Mutation (SNP) | VAF 78/234 reads (33%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.12); catalogued as COSV99783019; called by muse, mutect2, varscan2
- ANK3 | c.11596C>T p.P3866S | Missense Mutation (SNP) | VAF 126/386 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV99783021; called by muse, varscan2
- ANK3 | c.9673G>A p.E3225K | Missense Mutation (SNP) | VAF 61/205 reads (30%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0); catalogued as rs867499524, COSV55070593; called by muse, mutect2, varscan2
- ANK3 | c.9181C>T p.P3061S | Missense Mutation (SNP) | VAF 62/171 reads (36%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.992); catalogued as rs1299364308, COSV55044663; called by muse, mutect2, varscan2
- ANK3 | c.6118G>A p.D2040N | Missense Mutation (SNP) | VAF 71/213 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV55063968; called by muse, mutect2, varscan2
- ANK3 | c.5477C>T p.S1826F | Missense Mutation (SNP) | VAF 71/236 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV99783024; called by muse, mutect2, varscan2
- ANK3 | c.3134G>A p.R1045K (on ENST00000280772 / NM_001320874.2; = p.R179K on NM_001149.3) | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV99783027; called by muse, varscan2
- ANK3 | c.1693G>A p.G565R | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1186719801, COSV99782045; called by muse, mutect2, varscan2
- ANK3 | c.35G>A p.R12K | Missense Mutation (SNP) | VAF 45/168 reads (27%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.225); catalogued as COSV99783040; called by muse, mutect2, varscan2
- ANKEF1 | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 41/127 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.927); catalogued as rs755107512, COSV65691976; called by muse, mutect2, varscan2
- ANKEF1 | c.1180G>A p.E394K | Missense Mutation (SNP) | VAF 46/121 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.073); catalogued as COSV101001000, COSV101001094; called by muse, varscan2
- ANKEF1 | c.1642G>A p.G548R | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV101001097; called by muse, mutect2, varscan2
- ANKEF1 | c.2302C>T p.R768* | Nonsense Mutation (SNP) | VAF 24/103 reads (23%) | catalogued as rs767339625, COSV65691980; called by muse, mutect2, varscan2
- ANKFN1 | c.241C>T p.L81F | Missense Mutation (SNP) | VAF 41/193 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.564); catalogued as rs892200206, COSV100594368; called by muse, mutect2, varscan2
- ANKFN1 | c.373C>T p.R125W | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs763397126, COSV100593474, COSV100594369; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.6161C>T p.S2054F | Missense Mutation (SNP) | VAF 46/150 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.459); catalogued as rs146411620, COSV99784836; called by muse, mutect2, varscan2
- ANKRD1 | c.538G>A p.E180K | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as rs780993838, COSV63311064; called by muse, mutect2, varscan2
- ANKRD17 | c.1950T>G p.I650M | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV100430144; called by muse, mutect2, varscan2
- ANKRD29 | c.853A>T p.N285Y | Missense Mutation (SNP) | VAF 39/108 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as COSV99409338; called by muse, mutect2, varscan2
- ANKRD30A | c.565G>A p.E189K (on ENST00000611781; = p.E133K on NM_052997.2) | Missense Mutation (SNP) | VAF 30/118 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV100653302; called by muse, varscan2
- ANKRD30A | c.2959G>A p.G987R (on ENST00000611781; = p.G931R on NM_052997.2) | Missense Mutation (SNP) | VAF 30/104 reads (29%) | SIFT tolerated (0.4); PolyPhen benign (0.031); catalogued as COSV64606539, COSV64609460; called by muse, mutect2, varscan2
- ANKRD33 | c.466C>T p.P156S (on ENST00000340970 / NM_001304459.2; = p.P281S on NM_182608.4) | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.549); catalogued as rs1280994269, COSV100001595; called by muse, varscan2
- ANKRD34A | c.1138C>T p.P380S | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100041461; called by muse, mutect2, varscan2
- ANKRD35 | c.2047G>A p.E683K | Missense Mutation (SNP) | VAF 43/155 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100841884; called by muse, mutect2, varscan2
- ANKS1B | c.1096G>A p.E366K | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.275); catalogued as COSV100248941; called by muse, mutect2, varscan2
- ANKS1B | c.821C>T p.S274F | Missense Mutation (SNP) | VAF 39/106 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100248945, COSV61343842; called by muse, mutect2, varscan2
- ANKS4B | c.875G>A p.R292K | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as COSV100290002; called by muse, mutect2, varscan2
- ANO1 | c.2038G>A p.E680K | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV60282438; called by muse, mutect2, varscan2
- ANO10 | c.646G>A p.E216K | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.933); catalogued as COSV99429192; called by muse, mutect2, varscan2
- ANO2 | c.2845G>A p.E949K (on ENST00000356134 / NM_001278597.3; = p.E953K on NM_001278596.3) | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.837); catalogued as COSV100502647; called by muse, mutect2, varscan2
- ANO2 | c.2476C>T p.P826S (on ENST00000356134 / NM_001278597.3; = p.P830S on NM_001278596.3) | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100502649, COSV59016421; called by muse, mutect2, varscan2
- ANO2 | c.1579C>T p.R527C (on ENST00000356134 / NM_001278597.3; = p.R531C on NM_001278596.3) | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs779581544, COSV59044162; called by muse, varscan2
- ANO2 | c.1060G>A p.E354K (on ENST00000356134 / NM_001278597.3; = p.E358K on NM_001278596.3) | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV100500058, COSV100502654; called by muse, varscan2
- ANO3 | c.385G>A p.D129N | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV99886570; called by muse, mutect2, varscan2
- ANO3 | c.737G>A p.R246K | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT tolerated (0.6); PolyPhen benign (0.021); catalogued as COSV56781364; called by muse, mutect2, varscan2
- ANO4 | c.822A>C p.E274D (on ENST00000392977 / NM_001286615.2; = p.E239D on NM_178826.4) | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.87); catalogued as COSV100154109; called by muse, mutect2, varscan2
- ANO4 | c.823G>A p.E275K (on ENST00000392977 / NM_001286615.2; = p.E240K on NM_178826.4) | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT tolerated (0.36); PolyPhen benign (0.175); catalogued as COSV100153328, COSV100154110; called by muse, mutect2, varscan2
- ANO4 | c.899G>A p.G300E (on ENST00000392977 / NM_001286615.2; = p.G265E on NM_178826.4) | Missense Mutation (SNP) | VAF 54/167 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.221); catalogued as COSV54612507; called by muse, varscan2
- ANO4 | c.1757C>T p.S586F (on ENST00000392977 / NM_001286615.2; = p.S551F on NM_178826.4) | Missense Mutation (SNP) | VAF 33/97 reads (34%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.814); catalogued as COSV54602419; called by muse, mutect2, varscan2
- ANPEP | c.151C>T p.P51S | Missense Mutation (SNP) | VAF 53/194 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs762611345, COSV100263644; called by muse, mutect2, varscan2
- ANTXR1 | c.1345C>T p.P449S | Missense Mutation (SNP) | VAF 42/135 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100363281; called by muse, mutect2, varscan2
- ANTXR2 | c.1433G>A p.R478Q | Missense Mutation (SNP) | VAF 38/127 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as rs370094952, COSV101330396; called by muse, mutect2, varscan2
- ANXA1 | c.635G>A p.R212K | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1266264118, COSV99974139; called by muse, mutect2, varscan2
- ANXA9 | c.739G>A p.E247K | Missense Mutation (SNP) | VAF 39/155 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as COSV100929104, COSV100929183; called by muse, mutect2, varscan2
- AOAH | c.1060T>C p.L354= | Splice Region (SNP) | VAF 17/102 reads (17%) | catalogued as COSV51742270; called by muse, mutect2, varscan2
- AOC1 | c.1682G>A p.W561* | Nonsense Mutation (SNP) | VAF 10/64 reads (16%) | catalogued as COSV100711070; called by muse, mutect2, varscan2
- AOC1 | c.2062C>T p.P688S | Missense Mutation (SNP) | VAF 41/175 reads (23%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.961); catalogued as COSV100711071, COSV62867590; called by muse, mutect2, varscan2
- AOC1 | c.2063C>T p.P688L | Missense Mutation (SNP) | VAF 40/171 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.976); catalogued as COSV100711074; called by muse, mutect2, varscan2
- AOX1 | c.3447G>A p.M1149I | Missense Mutation (SNP) | VAF 40/131 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV53497240; called by muse, mutect2, varscan2
- AP002512.3 | c.587C>T p.S196F | Missense Mutation (SNP) | VAF 44/138 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.929); catalogued as rs751796790, COSV54406678; called by muse, varscan2
- AP3B2 | c.1732C>T p.R578W | Missense Mutation (SNP) | VAF 48/151 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs140388339, COSV99916689, COSV99917137; called by muse, mutect2, varscan2
- AP3D1 | c.735C>T p.F245= | Splice Region (SNP) | VAF 9/27 reads (33%) | catalogued as rs200473046; called by muse, mutect2, varscan2
- APBA2 | c.742G>A p.A248T | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.005); catalogued as COSV101382619, COSV68788998; called by muse, mutect2, varscan2
- APBA3 | c.515C>T p.P172L | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs374857161, COSV100349809; called by muse, mutect2, varscan2
- APBA3 | c.514C>T p.P172S | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.994); catalogued as COSV100349810; called by muse, mutect2, varscan2
- APCS | c.21G>A p.W7* | Nonsense Mutation (SNP) | VAF 81/165 reads (49%) | catalogued as COSV54817641; called by muse, mutect2, varscan2
- APCS | c.229G>A p.D77N | Missense Mutation (SNP) | VAF 81/177 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.118); catalogued as COSV54817181; called by muse, varscan2
- APCS | c.253G>A p.E85K | Missense Mutation (SNP) | VAF 42/184 reads (23%) | SIFT tolerated (0.44); PolyPhen benign (0.298); catalogued as rs770116180, COSV54817619, COSV99661119; called by muse, varscan2
- APCS | c.364G>A p.G122S | Missense Mutation (SNP) | VAF 54/141 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1472708041, COSV54817116; called by muse, mutect2, varscan2
- APCS | c.638G>A p.G213E | Missense Mutation (SNP) | VAF 66/139 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs771476250, COSV54817696; called by muse, mutect2, varscan2
- APEH | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 38/85 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.105); catalogued as rs571736407, COSV99610879, COSV99611213; called by muse, mutect2, varscan2
- API5 | c.596C>T p.S199F | Missense Mutation (SNP) | VAF 36/110 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); catalogued as COSV101124627; called by muse, mutect2, varscan2
- APOA4 | c.871G>A p.E291K | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.12); catalogued as COSV100759409; called by muse, mutect2, varscan2
- APOA4 | c.109C>T p.Q37* | Nonsense Mutation (SNP) | VAF 51/145 reads (35%) | catalogued as COSV100759410; called by muse, mutect2, varscan2
- APOB | c.12472C>T p.Q4158* | Nonsense Mutation (SNP) | VAF 57/175 reads (33%) | catalogued as COSV99268710; called by muse, mutect2, varscan2
- APOB | c.12352G>A p.G4118R | Missense Mutation (SNP) | VAF 101/270 reads (37%) | SIFT tolerated (0.68); PolyPhen benign (0.009); catalogued as COSV99268711; called by muse, mutect2, varscan2
- APOB | c.11164C>T p.P3722S | Missense Mutation (SNP) | VAF 70/225 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV51951307; called by muse, mutect2, varscan2
- APOB | c.10290A>T p.K3430N | Missense Mutation (SNP) | VAF 53/227 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.011); catalogued as COSV99268717; called by muse, mutect2, varscan2
- APOB | c.1478G>A p.G493E | Missense Mutation (SNP) | VAF 58/168 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV51922910; called by muse, varscan2
- APOBEC3C | c.214C>T p.L72F | Missense Mutation (SNP) | VAF 41/380 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.803); catalogued as rs748021941, COSV99329268; called by muse, varscan2
- APOBEC3D | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 65/219 reads (30%) | SIFT tolerated (0.76); PolyPhen benign (0.003); catalogued as rs746961335, COSV99329272; called by muse, mutect2, varscan2
- APOBEC3F | c.643G>A p.E215K | Missense Mutation (SNP) | VAF 82/225 reads (36%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.949); catalogued as rs761754118, COSV57909966; called by muse, mutect2, varscan2
- APOBR | c.859C>T p.P287S | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.033); catalogued as COSV100113013; called by muse, mutect2, varscan2
- APOF | c.733C>T p.L245F | Missense Mutation (SNP) | VAF 37/112 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100029196; called by muse, mutect2, varscan2
- AQP6 | c.392G>A p.G131E | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as COSV100210349; called by muse, mutect2
- AQR | c.4016C>T p.P1339L | Missense Mutation (SNP) | VAF 10/101 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.04); catalogued as rs1032677102, COSV99334950; called by muse, mutect2
- AQR | c.3223C>T p.P1075S | Missense Mutation (SNP) | VAF 35/121 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99334951; called by muse, mutect2, varscan2
- AR | c.2360G>A p.R787Q | Missense Mutation (SNP) | VAF 56/76 reads (74%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.921); catalogued as rs764684648, COSV65954300; called by muse, mutect2, varscan2
- ARAP2 | c.4211C>T p.S1404L | Missense Mutation (SNP) | VAF 60/204 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.129); catalogued as COSV58284890; called by muse, varscan2
- AREG | c.470G>A p.G157E | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99144409; called by muse, mutect2, varscan2
- ARFGAP3 | c.130C>T p.L44F | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99605650; called by muse, mutect2, varscan2
- ARFGEF2 | c.3313C>T p.P1105S | Missense Mutation (SNP) | VAF 60/154 reads (39%) | SIFT tolerated (0.47); PolyPhen benign (0.027); catalogued as COSV100904555; called by muse, mutect2, varscan2
- ARFGEF3 | c.5288C>T p.S1763F | Missense Mutation (SNP) | VAF 34/53 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs867571171, COSV99295007; called by muse, mutect2, varscan2
- ARHGAP1 | c.317+2T>G p.X106_splice | Splice Site (SNP) | VAF 4/35 reads (11%) | catalogued as COSV100358096; called by muse, mutect2, varscan2
- ARHGAP12 | c.542C>T p.P181L | Missense Mutation (SNP) | VAF 36/139 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.103); catalogued as COSV100260996; called by muse, mutect2, varscan2
- ARHGAP20 | c.2819C>T p.S940F | Missense Mutation (SNP) | VAF 36/112 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs1238569491, COSV99505759; called by muse, mutect2, varscan2
- ARHGAP21 | c.3944C>T p.T1315I | Missense Mutation (SNP) | VAF 19/184 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV57601710; called by muse, mutect2
- ARHGAP25 | c.1178G>A p.R393K (on ENST00000409202 / NM_001007231.3; = p.R385K on NM_014882.3) | Missense Mutation (SNP) | VAF 30/171 reads (18%) | SIFT tolerated (0.46); PolyPhen benign (0.006); catalogued as rs375730981; called by muse, mutect2, varscan2
- ARHGAP26 | c.1289C>T p.P430L | Missense Mutation (SNP) | VAF 69/349 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.597); catalogued as COSV99191141, COSV99191624; called by muse, mutect2, varscan2
- ARHGAP29 | c.2797G>A p.D933N | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.25); catalogued as COSV53111131; called by muse, mutect2, varscan2
- ARHGAP31 | c.463C>T p.H155Y | Missense Mutation (SNP) | VAF 69/200 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.355); catalogued as COSV99957919; called by muse, mutect2, varscan2
- ARHGAP33 | c.781C>T p.P261S | Missense Mutation (SNP) | VAF 36/200 reads (18%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as COSV99140560; called by muse, mutect2, varscan2
- ARHGAP33 | c.782C>T p.P261L | Missense Mutation (SNP) | VAF 36/201 reads (18%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as COSV99140569; called by muse, mutect2, varscan2
- ARHGAP33 | c.3082C>T p.P1028S | Missense Mutation (SNP) | VAF 58/166 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.021); catalogued as COSV99140471, COSV99140580; called by muse, mutect2, varscan2
- ARHGAP35 | c.2045G>A p.R682K | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.56); PolyPhen benign (0.073); catalogued as COSV101351928; called by muse, mutect2, varscan2
- ARHGAP35 | c.4190C>T p.S1397F | Missense Mutation (SNP) | VAF 133/409 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101351931; called by muse, mutect2, varscan2
- ARHGAP39 | c.2935C>T p.P979S (on ENST00000276826 / NM_001308208.2; = p.P1010S on NM_025251.2) | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99432514; called by muse, mutect2, varscan2
- ARHGAP6 | c.2687G>A p.W896* (on ENST00000337414 / NM_013427.3; = p.W693* on NM_013423.3) | Nonsense Mutation (SNP) | VAF 23/29 reads (79%) | catalogued as COSV100273684; called by muse, mutect2, varscan2
- ARHGAP9 | c.265C>T p.P89S | Missense Mutation (SNP) | VAF 77/251 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs768151689, COSV100712547; called by muse, mutect2, varscan2
- ARHGEF11 | c.1642C>T p.Q548* | Nonsense Mutation (SNP) | VAF 34/462 reads (7%) | catalogued as COSV100810453; called by muse, mutect2
- ARHGEF12 | c.1267C>T p.L423F | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.752); catalogued as rs759283013, COSV100755306; called by mutect2, varscan2
- ARHGEF15 | c.725C>T p.S242F | Missense Mutation (SNP) | VAF 61/202 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as rs1469244952, COSV100730218; called by muse, mutect2, varscan2
- ARHGEF17 | c.2542G>A p.E848K | Missense Mutation (SNP) | VAF 55/150 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.145); catalogued as rs1401742591, COSV99737191; called by muse, mutect2, varscan2
- ARHGEF17 | c.2861C>T p.S954F | Missense Mutation (SNP) | VAF 50/137 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.2); catalogued as COSV99737194; called by muse, mutect2, varscan2
- ARHGEF26 | c.1153G>T p.E385* | Nonsense Mutation (SNP) | VAF 15/41 reads (37%) | catalogued as COSV100726710; called by muse, mutect2, varscan2
- ARHGEF28 | c.4262C>T p.P1421L | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV99710446; called by muse, mutect2, varscan2
- ARHGEF35 | c.34C>T p.P12S | Missense Mutation (SNP) | VAF 57/226 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV100967817; called by muse, varscan2
- ARHGEF40 | c.890C>T p.P297L | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as COSV100070797; called by muse, mutect2, varscan2
- ARHGEF5 | c.709G>A p.E237K | Missense Mutation (SNP) | VAF 55/292 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV99283283; called by muse, mutect2, varscan2
- ARHGEF7 | c.1979C>T p.P660L (on ENST00000375741 / NM_001113511.2; = p.P482L on NM_003899.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1430553455, COSV99522311; called by muse, mutect2, varscan2
- ARID2 | c.461C>T p.S154L | Missense Mutation (SNP) | VAF 23/136 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.06); catalogued as rs554503964, COSV100537230; called by muse, mutect2, varscan2
- ARID2 | c.3437C>T p.S1146L | Missense Mutation (SNP) | VAF 34/132 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.642); catalogued as COSV57607135; called by muse, mutect2, varscan2
- ARID3C | c.794C>T p.P265L | Missense Mutation (SNP) | VAF 67/186 reads (36%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV99427111; called by muse, mutect2, varscan2
- ARMC12 | c.227C>T p.S76F (on ENST00000373866 / NM_001286574.2; = p.S103F on NM_145028.5) | Missense Mutation (SNP) | VAF 64/252 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV55361619; called by muse, varscan2
- ARMC4 | c.937G>A p.G313R | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as COSV99518162; called by muse, mutect2, varscan2
- ARMC4 | c.197C>T p.S66L | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.787); catalogued as COSV100537514; called by muse, mutect2, varscan2
- ARMC5 | c.332C>T p.P111L | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.076); catalogued as rs1473236430, COSV51659676; called by muse, varscan2
- ARPP19 | c.311C>T p.S104F | Missense Mutation (SNP) | VAF 67/182 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as COSV99993018; called by muse, mutect2, varscan2
- ARPP21 | c.2257G>A p.G753S | Missense Mutation (SNP) | VAF 47/120 reads (39%) | SIFT tolerated (0.53); PolyPhen benign (0.01); catalogued as rs1325902231, COSV99493771; called by muse, mutect2, varscan2
- ARSH | c.1082G>A p.G361E | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101140022; called by muse, mutect2, varscan2
- ARSJ | c.596C>T p.S199F | Missense Mutation (SNP) | VAF 100/272 reads (37%) | SIFT tolerated (0.69); PolyPhen benign (0.147); catalogued as COSV100193229; called by muse, mutect2, varscan2
- ASB15 | c.1255C>T p.P419S | Missense Mutation (SNP) | VAF 72/261 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99307101; called by muse, varscan2
- ASB2 | c.352G>A p.D118N | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated (0.46); PolyPhen benign (0.183); catalogued as rs144043383; called by muse, mutect2, varscan2
- ASB5 | c.698G>A p.W233* | Nonsense Mutation (SNP) | VAF 68/229 reads (30%) | catalogued as COSV99642232; called by muse, mutect2, varscan2
- ASB5 | c.377G>A p.G126E | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs775728346, COSV99642236; called by muse, mutect2, varscan2
- ASB5 | c.376G>A p.G126R | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV56673386, COSV99642239; called by muse, mutect2, varscan2
- ASCC3 | c.3773C>T p.P1258L | Missense Mutation (SNP) | VAF 70/99 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100226496; called by muse, mutect2, varscan2
- ASH1L | c.4513G>A p.G1505S | Missense Mutation (SNP) | VAF 30/160 reads (19%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.005); catalogued as COSV100853648; called by muse, mutect2, varscan2
- ASIC2 | c.987G>A p.G329= | Splice Region (SNP) | VAF 23/108 reads (21%) | catalogued as COSV99861380; called by muse, mutect2, varscan2
- ASIC2 | c.709G>A p.E237K | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99861384; called by muse, varscan2
- ASIC3 | c.530C>T p.T177I | Missense Mutation (SNP) | VAF 62/213 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs1160826273, COSV99875218; called by muse, mutect2, varscan2
- ASMT | c.257A>T p.N86I | Missense Mutation (SNP) | VAF 268/420 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101172572; called by muse, mutect2, varscan2
- ASNS | c.1018C>A p.R340S | Missense Mutation (SNP) | VAF 42/205 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99446363, COSV99446930; called by muse, mutect2, varscan2
- ASNS | c.518C>T p.P173L | Missense Mutation (SNP) | VAF 61/202 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs1456846689, COSV51550341; called by muse, mutect2, varscan2
- ASPA | c.304C>T p.P102S | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.469); catalogued as COSV53983316; called by muse, mutect2, varscan2
- ASPH | c.1588C>T p.H530Y | Missense Mutation (SNP) | VAF 101/398 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.77); catalogued as COSV101064599; called by muse, mutect2, varscan2
- ASTN1 | c.3437C>T p.P1146L | Missense Mutation (SNP) | VAF 44/118 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs865945553, COSV100708001, COSV100708026; called by muse, varscan2
- ASTN1 | c.3154G>A p.V1052M | Missense Mutation (SNP) | VAF 70/160 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.804); catalogued as COSV100708006; called by muse, mutect2, varscan2
- ASTN1 | c.2813G>A p.R938Q | Missense Mutation (SNP) | VAF 66/225 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0.012); catalogued as rs377472669, COSV100707710; called by muse, mutect2, varscan2
- ASTN1 | c.1585G>A p.D529N | Missense Mutation (SNP) | VAF 64/227 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.52); catalogued as COSV99920332; called by muse, mutect2, varscan2
- ASTN1 | c.779G>A p.G260E | Missense Mutation (SNP) | VAF 107/229 reads (47%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.998); catalogued as COSV99923533; called by muse, mutect2, varscan2
- ASTN1 | c.226G>T p.G76* | Nonsense Mutation (SNP) | VAF 37/62 reads (60%) | catalogued as COSV56063368, COSV99923535; called by muse, mutect2, varscan2
- ASTN2 | c.1579G>A p.D527N (on ENST00000313400 / NM_001365069.1; = p.D476N on NM_014010.5) | Missense Mutation (SNP) | VAF 29/118 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.51); catalogued as rs976057171, COSV57747261; called by muse, mutect2, varscan2
- ASXL3 | c.1027G>A p.E343K | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV99324027, COSV99326364; called by muse, mutect2, varscan2
- ASXL3 | c.3862A>G p.T1288A | Missense Mutation (SNP) | VAF 29/104 reads (28%) | SIFT tolerated, low confidence (0.83); PolyPhen benign (0); catalogued as COSV99327087; called by muse, mutect2, varscan2
- ASXL3 | c.4109C>T p.P1370L | Missense Mutation (SNP) | VAF 71/204 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.072); catalogued as COSV99327088; called by muse, mutect2, varscan2
- ATAD5 | c.68C>T p.P23L | Missense Mutation (SNP) | VAF 44/132 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.168); catalogued as COSV100430300; called by muse, mutect2, varscan2
- ATF5 | c.424C>T p.P142S | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT tolerated (0.4); PolyPhen benign (0.01); catalogued as rs1199101712, COSV61310991; called by muse, mutect2, varscan2
- ATF6B | c.1897C>T p.R633C | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.405); catalogued as rs1485410785, COSV100916861; called by muse, mutect2, varscan2
- ATF7IP2 | c.236C>T p.S79F | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV61092247; called by muse, varscan2
- ATL1 | c.556G>A p.D186N | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.352); catalogued as COSV100613362; called by muse, mutect2, varscan2
- ATP10A | c.2231C>T p.S744F | Missense Mutation (SNP) | VAF 35/143 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs267604143, COSV63523995; called by muse, mutect2, varscan2
- ATP10B | c.4273G>A p.E1425K | Missense Mutation (SNP) | VAF 18/186 reads (10%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.04); catalogued as rs1180562316, COSV100515969; called by muse, mutect2
- ATP12A | c.333G>A p.M111I | Missense Mutation (SNP) | VAF 247/666 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.055); catalogued as COSV99518745; called by muse, mutect2, varscan2
- ATP13A4 | c.2028G>A p.R676= | Splice Region (SNP) | VAF 16/136 reads (12%) | catalogued as COSV100710847; called by muse, mutect2, varscan2
- ATP13A4 | c.1772A>C p.E591A | Missense Mutation (SNP) | VAF 41/118 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.031); catalogued as COSV99795394; called by muse, mutect2, varscan2
- ATP13A5 | c.2339G>A p.G780E | Missense Mutation (SNP) | VAF 39/120 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.034); catalogued as COSV100665880; called by muse, mutect2, varscan2
- ATP13A5 | c.664G>A p.G222S | Missense Mutation (SNP) | VAF 44/118 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0.39); catalogued as COSV100665883; called by muse, mutect2, varscan2
- ATP1A2 | c.1630G>A p.G544R | Missense Mutation (SNP) | VAF 78/184 reads (42%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV63402548; called by muse, mutect2, varscan2
- ATP1A2 | c.1906G>A p.E636K | Missense Mutation (SNP) | VAF 37/156 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.12); catalogued as rs752936420, COSV100768232, COSV63405458; called by muse, mutect2, varscan2
- ATP1A2 | c.2699G>A p.G900E | Missense Mutation (SNP) | VAF 43/143 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100767696; called by muse, mutect2, varscan2
- ATP1A3 | c.460G>A p.E154K (on ENST00000545399 / NM_001256214.2; = p.E141K on NM_152296.5) | Missense Mutation (SNP) | VAF 49/203 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV57486362; called by muse, mutect2, varscan2
- ATP1B4 | c.100G>A p.D34N | Missense Mutation (SNP) | VAF 53/74 reads (72%) | SIFT tolerated, low confidence (0.21); PolyPhen probably damaging (0.984); catalogued as COSV99486634; called by muse, mutect2, varscan2
- ATP2A3 | c.1801G>A p.D601N | Missense Mutation (SNP) | VAF 43/146 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99989838; called by muse, mutect2, varscan2
- ATP2B1 | c.854G>C p.G285A | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99666323; called by muse, mutect2, varscan2
- ATP2B2 | c.1720G>A p.E574K (on ENST00000352432; = p.E540K on NM_001683.5) | Missense Mutation (SNP) | VAF 41/151 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.177); catalogued as rs764853768, COSV59505006; called by muse, mutect2, varscan2
- ATP2B2 | c.1340G>A p.G447E (on ENST00000352432; = p.G413E on NM_001683.5) | Missense Mutation (SNP) | VAF 35/103 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59504452; called by muse, mutect2, varscan2
- ATP2B2 | c.869G>A p.G290E | Missense Mutation (SNP) | VAF 97/317 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100660620; called by muse, mutect2, varscan2
- ATP2B2 | c.301G>A p.E101K | Missense Mutation (SNP) | VAF 142/551 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1559301935, COSV100660622; called by muse, mutect2, varscan2
- ATP2B3 | c.790G>A p.G264S | Missense Mutation (SNP) | VAF 27/50 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99686237; called by muse, mutect2, varscan2
- ATP2B3 | c.1798G>A p.G600R | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99686239; called by muse, mutect2, varscan2
- ATP2C1 | c.269C>T p.S90F | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100147060; called by muse, mutect2, varscan2
- ATP2C1 | c.1025G>A p.G342D | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100147064; called by muse, mutect2, varscan2
- ATP2C1 | c.1573C>T p.L525F | Missense Mutation (SNP) | VAF 51/137 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV100146993; called by muse, varscan2
- ATP6V0A4 | c.742C>T p.P248S | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.794); catalogued as COSV100023823; called by muse, mutect2, varscan2
- ATP6V0D2 | c.163G>A p.G55S | Missense Mutation (SNP) | VAF 94/238 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99572147; called by muse, mutect2, varscan2
- ATP6V1E2 | c.589G>A p.E197K | Missense Mutation (SNP) | VAF 68/202 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); catalogued as COSV100120854, COSV60576633; called by muse, varscan2
- ATP6V1G3 | c.214G>A p.E72K | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT tolerated (0.74); PolyPhen benign (0.068); catalogued as COSV55281031; called by muse, mutect2, varscan2
- ATP7B | c.3815C>T p.S1272F | Missense Mutation (SNP) | VAF 38/164 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54438095; called by muse, mutect2, varscan2
- ATP8A1 | c.3244G>C p.D1082H | Missense Mutation (SNP) | VAF 86/258 reads (33%) | SIFT tolerated (0.38); PolyPhen benign (0.037); catalogued as COSV100046386, COSV100047564; called by muse, mutect2, varscan2
- ATP8B4 | c.1972G>A p.E658K | Missense Mutation (SNP) | VAF 40/148 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.869); catalogued as COSV99468066; called by muse, mutect2, varscan2
- ATRX | c.2156C>T p.S719F | Missense Mutation (SNP) | VAF 33/222 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.365); catalogued as COSV64875166, COSV64883207; called by muse, mutect2, varscan2
- ATXN2L | c.3047C>T p.S1016F | Missense Mutation (SNP) | VAF 64/207 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.157); catalogued as rs866692986, COSV100295399; called by muse, mutect2, varscan2
- ATXN7 | c.2482C>T p.P828S | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT tolerated (0.72); PolyPhen benign (0.018); catalogued as rs1241022808, COSV99895577; called by muse, mutect2, varscan2
- AUTS2 | c.3049G>A p.G1017R | Missense Mutation (SNP) | VAF 39/82 reads (48%) | SIFT tolerated (0.41); PolyPhen benign (0.09); catalogued as COSV100719782; called by muse, mutect2, varscan2
- AVEN | c.404C>T p.S135L | Missense Mutation (SNP) | VAF 38/105 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.048); catalogued as rs1473037567, COSV100145958; called by muse, mutect2, varscan2
- AXDND1 | c.2587G>A p.E863K | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as COSV62639687; called by muse, mutect2, varscan2
- B3GALT2 | c.1034G>A p.G345E | Missense Mutation (SNP) | VAF 37/126 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100813649; called by muse, varscan2
- B3GALT4 | c.212C>T p.P71L | Missense Mutation (SNP) | VAF 67/303 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.11); catalogued as COSV101005740; called by muse, mutect2, varscan2
- B3GALT5 | c.1-1G>A p.X1_splice | Splice Site (SNP) | VAF 49/180 reads (27%) | catalogued as COSV100563520; called by muse, mutect2, varscan2
- B3GNT2 | c.386C>T p.S129L | Missense Mutation (SNP) | VAF 24/336 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.131); catalogued as COSV100114339; called by muse, mutect2
- B3GNT7 | c.718G>A p.D240N | Missense Mutation (SNP) | VAF 82/184 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774794596, COSV99806064; called by muse, mutect2, varscan2
- B3GNT8 | c.497C>T p.A166V | Missense Mutation (SNP) | VAF 53/164 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as rs1366835007, COSV99524838; called by muse, mutect2, varscan2
- B3GNTL1 | c.653G>A p.G218D | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as COSV100302301; called by muse, mutect2, varscan2
- B4GALNT2 | c.934G>A p.D312N | Missense Mutation (SNP) | VAF 105/280 reads (38%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.996); catalogued as rs35625808; called by muse, mutect2, varscan2
- BACH2 | c.2339C>T p.P780L | Missense Mutation (SNP) | VAF 61/158 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as COSV100001417; called by muse, mutect2, varscan2
- BAHCC1 | c.2582C>T p.P861L | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.925); catalogued as COSV57033636; called by muse, mutect2, varscan2
- BAHCC1 | c.5656G>A p.E1886K | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT tolerated (0.76); PolyPhen benign (0.133); catalogued as COSV100312152; called by muse, mutect2, varscan2
- BAHD1 | c.23C>T p.S8F | Missense Mutation (SNP) | VAF 18/265 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.77); catalogued as COSV69083977; called by muse, mutect2
- BAIAP2 | c.623C>T p.S208F | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT tolerated (0.71); PolyPhen benign (0.082); catalogued as COSV58335231, COSV58338802; called by muse, mutect2, varscan2
- BAIAP3 | c.811C>T p.P271S | Missense Mutation (SNP) | VAF 29/183 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100182026; called by muse, mutect2, varscan2
- BAIAP3 | c.3464G>A p.R1155K | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as COSV99136429; called by muse, mutect2, varscan2
- BARD1 | c.1360C>T p.P454S | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs730881408, COSV99640163; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BARD1 | c.1231C>T p.P411S | Missense Mutation (SNP) | VAF 31/122 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.522); catalogued as COSV53609132; called by muse, mutect2, varscan2
- BARX2 | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.664); catalogued as COSV99859111; called by muse, varscan2
- BATF2 | c.793C>T p.P265S | Missense Mutation (SNP) | VAF 44/111 reads (40%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV57251268; called by muse, mutect2, varscan2
- BATF2 | c.331C>T p.P111S | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.057); catalogued as rs1209921978, COSV100101941; called by muse, mutect2
- BAZ1A | c.2110G>T p.G704W | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100701239; called by muse, mutect2, varscan2
- BAZ1B | c.2163T>G p.D721E | Missense Mutation (SNP) | VAF 48/210 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.141); catalogued as COSV100290235; called by muse, mutect2, varscan2
- BAZ2A | c.1349C>T p.S450F | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.038); catalogued as COSV99468115; called by muse, mutect2, varscan2
- BAZ2B | c.4759C>A p.Q1587K | Missense Mutation (SNP) | VAF 43/123 reads (35%) | SIFT tolerated (0.59); PolyPhen benign (0.158); catalogued as COSV100601161; called by muse, mutect2, varscan2
- BAZ2B | c.4234G>A p.E1412K | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.985); catalogued as COSV100601163; called by muse, mutect2
- BBS10 | c.1513C>T p.P505S | Missense Mutation (SNP) | VAF 16/247 reads (6%) | SIFT tolerated (0.3); PolyPhen benign (0.055); catalogued as COSV101283351, COSV67913150; called by muse, mutect2
- BBS12 | c.245G>A p.R82K | Missense Mutation (SNP) | VAF 42/130 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100045143; called by muse, mutect2, varscan2
- BBX | c.1519C>T p.P507S | Missense Mutation (SNP) | VAF 54/141 reads (38%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.999); catalogued as COSV100362393; called by muse, mutect2, varscan2
- BBX | c.2642G>A p.G881E (on ENST00000325805 / NM_001142568.3; = p.G851E on NM_020235.7) | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100362394; called by muse, mutect2, varscan2
- BCAM | c.958G>A p.G320R | Missense Mutation (SNP) | VAF 31/113 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.307); catalogued as COSV99539073; called by muse, mutect2, varscan2
- BCAM | c.959G>A p.G320E | Missense Mutation (SNP) | VAF 31/113 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.927); catalogued as rs1465639483, COSV99539076; called by muse, mutect2, varscan2
- BCAM | c.1490C>T p.P497L | Missense Mutation (SNP) | VAF 47/177 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as COSV54301283; called by muse, mutect2, varscan2
- BCL11B | c.1769A>G p.E590G (on ENST00000357195 / NM_001282237.2; = p.E519G on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV100596025; called by muse, varscan2
- BCL11B | c.1768G>C p.E590Q (on ENST00000357195 / NM_001282237.2; = p.E519Q on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.033); catalogued as COSV100596026, COSV61735188; called by muse, varscan2
- BCL6B | c.862C>T p.P288S | Missense Mutation (SNP) | VAF 63/239 reads (26%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as COSV99546967; called by muse, mutect2, varscan2
- BCL6B | c.1307G>A p.G436E | Missense Mutation (SNP) | VAF 39/132 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99546973; called by muse, mutect2, varscan2
- BCLAF1 | c.674C>T p.S225L | Missense Mutation (SNP) | VAF 27/216 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs867887734, COSV62141504; called by muse, varscan2
- BCLAF1 | c.489A>T p.E163D | Missense Mutation (SNP) | VAF 42/315 reads (13%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.01); catalogued as COSV100787150, COSV62141017; called by muse, mutect2, varscan2
- BCORL1 | c.815C>T p.S272L | Missense Mutation (SNP) | VAF 81/126 reads (64%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.32); catalogued as rs1263318954, COSV54406776; called by muse, mutect2, varscan2
- BCR | c.1412G>A p.R471K | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.114); catalogued as rs1170250956, COSV100007226; called by muse, mutect2, varscan2
- BCR | c.1885G>A p.D629N | Missense Mutation (SNP) | VAF 29/112 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.043); catalogued as COSV59928918; called by muse, mutect2, varscan2
- BDKRB1 | c.973G>A p.E325K | Missense Mutation (SNP) | VAF 131/386 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.21); catalogued as COSV53706803; called by muse, mutect2, varscan2
- BDP1 | c.7352C>T p.S2451F | Missense Mutation (SNP) | VAF 44/122 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as COSV100703697; called by muse, mutect2, varscan2
- BEGAIN | c.1699G>A p.A567T | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.461); catalogued as COSV100767043; called by muse, mutect2, varscan2
- BEND4 | c.794C>A p.P265Q | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated, low confidence (0.96); PolyPhen benign (0); catalogued as COSV101549811; called by muse, mutect2, varscan2
- BEND7 | c.853G>A p.G285R | Missense Mutation (SNP) | VAF 60/190 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100347121; called by muse, varscan2
- BEND7 | c.740C>T p.S247F | Missense Mutation (SNP) | VAF 38/138 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs768901330, COSV100347122; called by muse, varscan2
- BHMT2 | c.968G>A p.G323E | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs376104626; called by muse, mutect2, varscan2
- BICC1 | c.2728C>T p.Q910* | Nonsense Mutation (SNP) | VAF 11/142 reads (8%) | catalogued as COSV100875025; called by muse, mutect2
- BICDL1 | c.1126C>T p.R376C | Missense Mutation (SNP) | VAF 58/162 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs778194508, COSV57492503; called by muse, mutect2, varscan2
- BICRA | c.3614C>T p.S1205F | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.428); catalogued as COSV101194513; called by muse, mutect2, varscan2
- BICRAL | c.1609C>T p.P537S | Missense Mutation (SNP) | VAF 24/117 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.022); catalogued as COSV100018619; called by muse, mutect2, varscan2
- BLM | c.1003C>T p.L335F | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0.3); catalogued as COSV100757372; called by muse, mutect2, varscan2
- BLNK | c.890C>T p.P297L | Missense Mutation (SNP) | VAF 32/151 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.629); catalogued as COSV99814315; called by muse, mutect2, varscan2
- BLNK | c.520G>A p.D174N | Missense Mutation (SNP) | VAF 65/187 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.219); catalogued as rs782646551, COSV99814320; called by muse, mutect2, varscan2
- BMP1 | c.2429G>A p.G810E | Missense Mutation (SNP) | VAF 12/194 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs886062819, COSV100115527; ClinVar: uncertain significance; called by muse, mutect2
- BMP10 | c.92C>T p.P31L | Missense Mutation (SNP) | VAF 42/150 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.024); catalogued as rs936341266, COSV99770678; called by muse, varscan2
- BMP15 | c.919C>T p.H307Y | Missense Mutation (SNP) | VAF 58/96 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs782540417, COSV99399579; called by muse, mutect2, varscan2
- BMP2 | c.866G>A p.R289Q | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); catalogued as rs370948498, COSV66577849; called by muse, mutect2, varscan2
- BMP2K | c.1877C>T p.P626L | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100622069; called by muse, mutect2, varscan2
- BMP3 | c.1169C>T p.S390F | Missense Mutation (SNP) | VAF 73/226 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99261876; called by muse, mutect2, varscan2
- BMP7 | c.955G>A p.A319T | Missense Mutation (SNP) | VAF 63/157 reads (40%) | SIFT tolerated (0.71); PolyPhen benign (0.009); catalogued as COSV101216359; called by muse, mutect2, varscan2
- BMPER | c.1177G>A p.D393N | Missense Mutation (SNP) | VAF 77/243 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99780830; called by muse, mutect2, varscan2
- BMPER | c.1877-1G>A p.X626_splice | Splice Site (SNP) | VAF 98/230 reads (43%) | catalogued as rs1255158794, COSV99780833; called by muse, mutect2, varscan2
- BMT2 | c.739C>T p.L247F | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99774931; called by muse, mutect2, varscan2
- BNC1 | c.791A>T p.Y264F | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as COSV100597562; called by muse, mutect2, varscan2
- BNC1 | c.194C>T p.A65V | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV100597564; called by muse, mutect2, varscan2
- BPGM | c.751C>T p.Q251* | Nonsense Mutation (SNP) | VAF 35/186 reads (19%) | catalogued as COSV100790237; called by muse, mutect2, varscan2
- BPIFA2 | c.551C>T p.S184F | Missense Mutation (SNP) | VAF 56/213 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV53612384; called by muse, mutect2, varscan2
- BPIFB2 | c.1150G>A p.D384N | Missense Mutation (SNP) | VAF 41/167 reads (25%) | SIFT tolerated (0.33); PolyPhen benign (0.046); catalogued as COSV50063279; called by muse, mutect2, varscan2
- BPNT2 | c.451C>T p.P151S | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.582); catalogued as COSV99389327; called by muse, mutect2
- BPTF | c.3616G>A p.E1206K | Missense Mutation (SNP) | VAF 57/98 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs753831908, COSV100076333; called by muse, mutect2, varscan2
- BRD2 | c.802C>T p.P268S | Missense Mutation (SNP) | VAF 33/139 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.024); catalogued as rs752511803, COSV100875883, COSV66373066; called by muse, mutect2, varscan2
- BRD4 | c.3734C>T p.A1245V | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.048); catalogued as rs1293348757, COSV54587214; called by muse, mutect2, varscan2
- BRD4 | c.646C>T p.P216S | Missense Mutation (SNP) | VAF 92/341 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.068); catalogued as rs758207588, COSV99651607; called by muse, mutect2, varscan2
- BRDT | c.1502C>T p.S501F | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.602); catalogued as COSV100746636, COSV62865866; called by muse, mutect2, varscan2
- BRINP1 | c.2105G>A p.R702Q | Missense Mutation (SNP) | VAF 55/173 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV56297833; called by muse, mutect2, varscan2
- BRINP1 | c.1927C>T p.P643S | Missense Mutation (SNP) | VAF 89/283 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.758); catalogued as COSV56296860; called by muse, mutect2, varscan2
- BRINP3 | c.1700C>T p.P567L | Missense Mutation (SNP) | VAF 86/200 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100819616, COSV66526610; called by muse, mutect2, varscan2
- BRINP3 | c.155G>A p.G52E | Missense Mutation (SNP) | VAF 36/83 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs867393057, COSV100818417, COSV100819618; called by muse, mutect2, varscan2
- BRPF3 | c.1045C>T p.H349Y | Missense Mutation (SNP) | VAF 56/90 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100325743, COSV60206911; called by muse, mutect2, varscan2
- BRS3 | c.610A>T p.T204S | Missense Mutation (SNP) | VAF 35/52 reads (67%) | SIFT tolerated (0.36); PolyPhen benign (0.102); catalogued as COSV101036712; called by muse, mutect2, varscan2
- BSN | c.2318C>T p.S773F | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56519192; called by muse, mutect2, varscan2
- BSN | c.4463G>A p.S1488N | Missense Mutation (SNP) | VAF 56/182 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as COSV99610162; called by muse, mutect2, varscan2
- BSND | c.439G>A p.G147R | Missense Mutation (SNP) | VAF 38/124 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0.027); catalogued as COSV100987667; called by muse, mutect2, varscan2
- BTBD11 | c.296G>A p.W99* | Nonsense Mutation (SNP) | VAF 5/18 reads (28%) | catalogued as COSV99777238; called by muse, mutect2
- BTBD16 | c.232G>A p.G78R | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as COSV53262020; called by muse, mutect2, varscan2
- BTBD16 | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 90/234 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.306); catalogued as COSV53267448; called by muse, mutect2, varscan2
- BTBD16 | c.1439C>T p.S480F | Missense Mutation (SNP) | VAF 36/100 reads (36%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.461); catalogued as rs1417244505, COSV99585395; called by muse, varscan2
- BTBD17 | c.1354T>A p.S452T | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV64730844; called by muse, mutect2, varscan2
- BTBD7 | c.2422C>T p.P808S | Missense Mutation (SNP) | VAF 37/98 reads (38%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.009); catalogued as rs946708889, COSV100598305; called by muse, mutect2, varscan2
- BTBD7 | c.1307C>T p.S436L | Missense Mutation (SNP) | VAF 49/143 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs780909487, COSV58283320; called by muse, mutect2, varscan2
- BTN2A1 | c.1442C>T p.S481F | Missense Mutation (SNP) | VAF 60/262 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.049); catalogued as rs1173508454, COSV57002071; called by muse, mutect2, varscan2
- BTN3A3 | c.1648G>A p.E550K | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV99765072; called by muse, mutect2, varscan2
- BTNL2 | c.1063G>A p.D355N | Missense Mutation (SNP) | VAF 41/132 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.881); catalogued as COSV100896255; called by muse, mutect2, varscan2
- BTNL9 | c.438G>A p.W146* | Nonsense Mutation (SNP) | VAF 22/80 reads (28%) | catalogued as COSV59797153; called by muse, varscan2
- BUB1 | c.2029C>T p.R677C | Missense Mutation (SNP) | VAF 37/96 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs867863036, COSV57062533; called by muse, mutect2, varscan2
- C10orf120 | c.787C>T p.R263C | Missense Mutation (SNP) | VAF 114/170 reads (67%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs748398816, COSV100271529; called by muse, mutect2, varscan2
- C10orf71 | c.673C>T p.P225S | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated (0.46); PolyPhen benign (0.013); catalogued as COSV100110758; called by muse, mutect2, varscan2
- C10orf99 | c.161-1G>A p.X54_splice | Splice Site (SNP) | VAF 46/162 reads (28%) | catalogued as COSV64531756; called by muse, mutect2, varscan2
- C11orf94 | c.131C>T p.S44F | Missense Mutation (SNP) | VAF 48/142 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.678); catalogued as COSV53797769, COSV99571863; called by muse, mutect2, varscan2
- C12orf40 | c.1186G>A p.D396N | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as rs1246749812, COSV100210923; called by muse, mutect2, varscan2
- C12orf50 | c.1102G>A p.E368K | Missense Mutation (SNP) | VAF 58/164 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.359); catalogued as rs1455692948, COSV53895400; called by muse, varscan2
- C12orf54 | c.25C>T p.Q9* | Nonsense Mutation (SNP) | VAF 18/70 reads (26%) | catalogued as COSV100011702; called by muse, mutect2, varscan2
- C12orf54 | c.284G>A p.R95K | Missense Mutation (SNP) | VAF 59/183 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV100011703, COSV58360234; called by muse, mutect2, varscan2
- C14orf93 | c.1061A>T p.N354I | Missense Mutation (SNP) | VAF 39/130 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.962); catalogued as COSV54440953; called by muse, mutect2, varscan2
- C15orf39 | c.160G>A p.G54S | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT tolerated (0.36); PolyPhen benign (0.031); catalogued as COSV100641523; called by muse, mutect2, varscan2
- C15orf39 | c.1235C>T p.A412V | Missense Mutation (SNP) | VAF 60/187 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.456); catalogued as rs537106521, COSV100641524; called by muse, mutect2, varscan2
- C16orf78 | c.19G>A p.D7N | Missense Mutation (SNP) | VAF 45/95 reads (47%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV100148042; called by muse, mutect2, varscan2
- C16orf78 | c.607G>A p.E203K | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as rs867806225, COSV54558762; called by muse, varscan2
- C16orf82 | c.41G>A p.G14E | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT tolerated (0.8); PolyPhen benign (0.103); catalogued as rs1028055238; called by muse, mutect2, varscan2
- C1QTNF9B | c.428G>A p.G143E | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); catalogued as COSV101158655; called by muse, varscan2
- C1QTNF9B | c.346G>A p.G116R | Missense Mutation (SNP) | VAF 33/164 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753481508, COSV101158656; called by muse, varscan2
- C1QTNF9B | c.310G>A p.G104R | Missense Mutation (SNP) | VAF 38/189 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65943899; called by muse, varscan2
- C1R | c.106C>T p.P36S (on ENST00000536053 / NM_001354346.2; = p.P22S on NM_001733.7) | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.014); catalogued as COSV99865040; called by muse, mutect2, varscan2
- C1RL | c.1376G>A p.G459D | Missense Mutation (SNP) | VAF 41/120 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1464887813, COSV56927345; called by muse, mutect2, varscan2
- C1S | c.1732C>T p.R578C | Missense Mutation (SNP) | VAF 40/80 reads (50%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.47); catalogued as rs781818479, COSV61072007; called by muse, mutect2, varscan2
- C1orf105 | c.26C>T p.S9F | Missense Mutation (SNP) | VAF 57/98 reads (58%) | SIFT tolerated (0.17); PolyPhen benign (0.035); catalogued as COSV99278410; called by muse, mutect2, varscan2
- C1orf127 | c.2357G>A p.G786E | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100983523; called by muse, mutect2, varscan2
- C1orf141 | c.355G>A p.E119K | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.078); catalogued as COSV100924414; called by muse, mutect2, varscan2
- C1orf158 | c.422G>A p.G141E | Missense Mutation (SNP) | VAF 35/162 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.944); catalogued as COSV55346323, COSV99847215; called by muse, varscan2
- C1orf50 | c.562C>T p.P188S | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.01); catalogued as COSV100998159; called by muse, mutect2, varscan2
- C1orf50 | c.563C>T p.P188L | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); catalogued as rs762133303, COSV65308390, COSV65308504; called by muse, mutect2, varscan2
- C1orf56 | c.113T>A p.L38* | Nonsense Mutation (SNP) | VAF 30/85 reads (35%) | catalogued as COSV99764864; called by muse, mutect2, varscan2
- C20orf96 | c.668C>T p.S223F (on ENST00000360321 / NM_153269.3; = p.S222F on NM_080571.1) | Missense Mutation (SNP) | VAF 90/354 reads (25%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.826); catalogued as rs199526456; called by muse, mutect2, varscan2
- C22orf42 | c.98C>T p.P33L | Missense Mutation (SNP) | VAF 36/166 reads (22%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.261); catalogued as COSV101173397; called by muse, mutect2, varscan2
- C2orf16 | c.4735G>A p.E1579K | Missense Mutation (SNP) | VAF 71/235 reads (30%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.513); catalogued as COSV100821131; called by muse, varscan2
- C2orf16 | c.4792C>T p.H1598Y | Missense Mutation (SNP) | VAF 56/198 reads (28%) | SIFT tolerated (0.54); PolyPhen benign (0.046); catalogued as COSV100821132; called by muse, varscan2
- C2orf73 | c.392C>T p.P131L | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1188989422, COSV100471536; called by muse, mutect2
- C2orf78 | c.2309C>T p.P770L | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.523); catalogued as COSV101281040; called by muse, mutect2, varscan2
- C2orf78 | c.2693C>T p.S898F | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV101281041, COSV68519057; called by muse, mutect2, varscan2
- C3 | c.3640G>A p.A1214T | Missense Mutation (SNP) | VAF 108/379 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.816); catalogued as COSV99837443; called by muse, mutect2, varscan2
- C3 | c.2593G>A p.E865K | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.937); catalogued as COSV55573399; called by muse, mutect2, varscan2
- C3 | c.2521C>T p.R841* | Nonsense Mutation (SNP) | VAF 24/85 reads (28%) | catalogued as rs772142244, COSV55575021, COSV99836202; called by muse, mutect2, varscan2
- C3orf56 | c.338C>T p.P113L | Missense Mutation (SNP) | VAF 85/298 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.031); catalogued as COSV101228986; called by muse, mutect2, varscan2
- C4orf17 | c.302C>T p.P101L | Missense Mutation (SNP) | VAF 46/108 reads (43%) | SIFT tolerated (0.44); PolyPhen benign (0.006); catalogued as COSV100431163; called by muse, mutect2, varscan2
- C5 | c.2495C>T p.S832F | Missense Mutation (SNP) | VAF 45/132 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99799019; called by muse, mutect2, varscan2
- C6 | c.2633C>T p.S878F | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as rs1244070672, COSV54710373; called by muse, mutect2, varscan2
- C6 | c.2611G>A p.E871K | Missense Mutation (SNP) | VAF 120/551 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs865941754, COSV54707096; called by muse, mutect2, varscan2
- C6 | c.2284G>A p.E762K | Missense Mutation (SNP) | VAF 32/144 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0.01); catalogued as COSV54705990; called by muse, mutect2, varscan2
- C6 | c.1636G>A p.G546S | Missense Mutation (SNP) | VAF 70/270 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99668004; called by muse, varscan2
- C6 | c.1067G>A p.R356Q | Missense Mutation (SNP) | VAF 30/155 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.098); catalogued as rs369381506; called by muse, varscan2
- C6 | c.1037C>T p.P346L | Missense Mutation (SNP) | VAF 37/160 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99668006; called by muse, varscan2
- C6 | c.172G>A p.E58K | Missense Mutation (SNP) | VAF 48/185 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs769744623, COSV54708891; called by muse, mutect2, varscan2
- C6orf58 | c.952C>T p.H318Y | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as COSV100315098; called by muse, mutect2, varscan2
- C7 | c.239C>T p.P80L | Missense Mutation (SNP) | VAF 49/218 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57472311; called by muse, mutect2, varscan2
- C7 | c.422G>A p.G141E | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs977493333, COSV57471713; called by muse, mutect2, varscan2
- C7 | c.1645G>A p.E549K | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.82); catalogued as rs1412761275, COSV100496778; called by muse, mutect2, varscan2
- C7 | c.1768C>T p.P590S | Missense Mutation (SNP) | VAF 33/137 reads (24%) | SIFT tolerated (0.15); PolyPhen probably damaging (1); catalogued as COSV57471459; called by muse, mutect2, varscan2
- C7 | c.2527C>T p.Q843* | Nonsense Mutation (SNP) | VAF 10/48 reads (21%) | catalogued as COSV100496780; called by muse, mutect2, varscan2
- C8A | c.725A>T p.K242I | Missense Mutation (SNP) | VAF 31/129 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.127); catalogued as COSV100776700; called by muse, mutect2, varscan2
- C8B | c.1495G>A p.E499K | Missense Mutation (SNP) | VAF 58/94 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64776698; called by muse, mutect2, varscan2
- C8B | c.1003G>A p.D335N | Missense Mutation (SNP) | VAF 36/106 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.386); catalogued as rs750289971, COSV100980955; called by muse, mutect2, varscan2
- C8B | c.534G>A p.G178= | Splice Region (SNP) | VAF 69/198 reads (35%) | catalogued as COSV64777626; called by muse, mutect2, varscan2
- C8orf34 | c.1306G>A p.E436K | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated (0.43); PolyPhen benign (0.055); catalogued as COSV57398183; called by muse, mutect2, varscan2
- C8orf74 | c.826G>A p.E276K | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.234); catalogued as rs1205612448; called by muse, mutect2
- C9 | c.811C>T p.R271W | Missense Mutation (SNP) | VAF 30/210 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as rs757060107, COSV54676570; called by muse, varscan2
- C9 | c.394G>A p.D132N | Missense Mutation (SNP) | VAF 57/412 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.147); catalogued as COSV99662703; called by muse, varscan2
- C9 | c.386C>T p.S129L | Missense Mutation (SNP) | VAF 44/418 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748961206, COSV99662708; called by muse, varscan2
- C9orf131 | c.2014G>A p.E672K | Missense Mutation (SNP) | VAF 43/117 reads (37%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as COSV100398382; called by muse, mutect2, varscan2
- CA11 | c.803C>T p.S268F | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV99320926; called by muse, mutect2, varscan2
- CA11 | c.325T>A p.F109I | Missense Mutation (SNP) | VAF 40/164 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.338); catalogued as COSV99320931; called by muse, mutect2, varscan2
- CA8 | c.127G>A p.D43N | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0.09); catalogued as COSV100527384; called by muse, mutect2
- CABCOCO1 | c.241G>A p.E81K | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs1258363838, COSV100358135; called by muse, mutect2, varscan2
- CABIN1 | c.4898C>T p.P1633L | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99574076, COSV99574232; called by muse, mutect2, varscan2
- CABP5 | c.220C>T p.Q74* | Nonsense Mutation (SNP) | VAF 32/103 reads (31%) | catalogued as COSV99506785; called by muse, mutect2, varscan2
- CACNA1A | c.2764G>A p.G922S | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.079); catalogued as COSV100803491; called by muse, mutect2, varscan2
- CACNA1A | c.1567G>A p.E523K | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV64191217; called by muse, mutect2, varscan2
- CACNA1B | c.644C>T p.S215F | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99500561; called by muse, mutect2, varscan2
- CACNA1B | c.5191C>T p.R1731W | Missense Mutation (SNP) | VAF 45/93 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53112622, COSV53129874; called by muse, mutect2, varscan2
- CACNA1C | c.1814T>G p.L605R | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100223482; called by muse, mutect2, varscan2
- CACNA1C | c.2536G>A p.E846K | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.079); catalogued as rs1295351612, COSV100223488; called by muse, mutect2, varscan2
- CACNA1C | c.2764C>T p.P922S | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100223496; called by muse, mutect2, varscan2
- CACNA1D | c.1352A>G p.E451G | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.084); catalogued as COSV99860520; called by muse, mutect2
- CACNA1E | c.5962G>A p.D1988N | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.119); catalogued as COSV100705964; called by muse, mutect2, varscan2
- CACNA1E | c.6274C>T p.L2092F (on ENST00000367573 / NM_001205293.3; = p.L2049F on NM_000721.4) | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated (0.7); PolyPhen probably damaging (0.988); catalogued as COSV100705968; called by muse, mutect2, varscan2
- CACNA1H | c.6697G>A p.E2233K | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); catalogued as COSV99327182; called by muse, mutect2, varscan2
- CACNA1I | c.1484G>A p.G495E | Missense Mutation (SNP) | VAF 53/133 reads (40%) | SIFT tolerated (0.4); PolyPhen benign (0.021); catalogued as rs768984965, COSV100361864; called by muse, mutect2, varscan2
- CACNA1S | c.5370G>A p.K1790= | Splice Region (SNP) | VAF 21/93 reads (23%) | catalogued as COSV100755463; called by muse, mutect2, varscan2
- CACNA2D2 | c.305G>A p.R102Q | Missense Mutation (SNP) | VAF 53/156 reads (34%) | SIFT tolerated (0.4); PolyPhen benign (0.246); catalogued as rs376677841; called by muse, mutect2, varscan2
- CACNA2D3 | c.1837C>T p.P613S | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs867317108, COSV55518389, COSV99878037; called by muse, varscan2
- CACNA2D4 | c.910G>A p.G304R | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99766793; called by muse, mutect2, varscan2
- CACNG5 | c.812C>T p.S271F | Missense Mutation (SNP) | VAF 39/161 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.037); catalogued as rs150302406; called by muse, mutect2, varscan2
- CACNG7 | c.202G>A p.E68K | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (0.7); PolyPhen benign (0.009); catalogued as rs1464449816, COSV55817810, COSV99712384; called by muse, mutect2, varscan2
- CADM1 | c.1078G>A p.D360N | Missense Mutation (SNP) | VAF 51/95 reads (54%) | SIFT tolerated (0.27); PolyPhen benign (0.012); catalogued as COSV100523640; called by muse, mutect2, varscan2
- CADM2 | c.949C>T p.P317S (on ENST00000407528 / NM_001167674.2; = p.P319S on NM_153184.4) | Missense Mutation (SNP) | VAF 84/316 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV67359479; called by muse, mutect2, varscan2
- CADM4 | c.774G>A p.W258* | Nonsense Mutation (SNP) | VAF 28/68 reads (41%) | catalogued as COSV55928478; called by muse, mutect2, varscan2
- CADPS | c.3137C>T p.S1046L | Missense Mutation (SNP) | VAF 68/186 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs373178609; called by muse, mutect2, varscan2
- CADPS | c.1522C>T p.L508F | Missense Mutation (SNP) | VAF 42/167 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs866121744, COSV99340323, COSV99341560; called by muse, mutect2, varscan2
- CADPS2 | c.2707C>T p.P903S | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100466744; called by muse, mutect2, varscan2
- CADPS2 | c.2201G>A p.G734E | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100466750, COSV100467259; called by muse, mutect2, varscan2
- CADPS2 | c.496G>A p.G166R | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100466755; called by muse, mutect2, varscan2
- CAGE1 | c.658C>T p.P220S (on ENST00000512086; = p.P84S on NM_205864.3) | Missense Mutation (SNP) | VAF 81/377 reads (21%) | SIFT tolerated (0.32); PolyPhen benign (0.011); catalogued as rs1276652333, COSV99700287; called by muse, mutect2, varscan2
- CALCB | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 22/39 reads (56%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1287429351, COSV100158171; called by muse, mutect2, varscan2
- CALCRL | c.1220G>A p.G407E | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0.02); catalogued as COSV101131056, COSV66476376; called by muse, mutect2, varscan2
- CALCRL | c.103G>A p.G35R | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as COSV101131059; called by muse, varscan2
- CALHM5 | c.415G>A p.E139K | Missense Mutation (SNP) | VAF 52/83 reads (63%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as COSV62067430; called by muse, mutect2, varscan2
- CALR3 | c.1003G>A p.E335K | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT tolerated (0.95); PolyPhen benign (0.06); catalogued as rs199535524; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CAMK1G | c.310G>A p.E104K | Missense Mutation (SNP) | VAF 106/243 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV99152400; called by muse, mutect2, varscan2
- CAMK1G | c.790G>A p.E264K | Missense Mutation (SNP) | VAF 43/116 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs770539963, COSV50521955; called by muse, mutect2, varscan2
- CAMK2G | c.581C>T p.P194L | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1485575876, COSV99990517; called by muse, mutect2, varscan2
- CAMK2G | c.212C>T p.P71L | Missense Mutation (SNP) | VAF 49/159 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV99990101, COSV99990522; called by muse, mutect2, varscan2
- CAMK2N1 | c.46G>A p.G16S | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.139); catalogued as COSV100907038; called by muse, mutect2, varscan2
- CAMKK1 | c.974C>T p.S325F | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.489); catalogued as COSV99340658; called by muse, mutect2, varscan2
- CAMKV | c.855G>A p.W285* | Nonsense Mutation (SNP) | VAF 24/88 reads (27%) | catalogued as COSV99616150; called by muse, mutect2, varscan2
- CAMSAP1 | c.4780G>A p.V1594M | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.58); catalogued as COSV100410515; called by muse, mutect2, varscan2
- CAMSAP3 | c.3418G>A p.E1140K | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); catalogued as COSV50335313, COSV99350041; called by muse, mutect2, varscan2
- CAMTA1 | c.3413C>T p.S1138L | Missense Mutation (SNP) | VAF 79/222 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.222); catalogued as rs750477632, COSV100349793; called by muse, mutect2, varscan2
- CAPN13 | c.1094C>T p.P365L | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs866646904, COSV99701283; called by muse, mutect2, varscan2
- CAPN13 | c.1093C>T p.P365S | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as COSV99701285; called by muse, mutect2, varscan2
- CAPN6 | c.1787T>C p.V596A | Missense Mutation (SNP) | VAF 44/63 reads (70%) | SIFT tolerated (0.44); PolyPhen benign (0.012); catalogued as COSV100137156; called by muse, mutect2, varscan2
- CAPN6 | c.787C>T p.R263C | Missense Mutation (SNP) | VAF 266/374 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV60695041; called by muse, mutect2, varscan2
- CAPN9 | c.1546G>A p.E516K | Missense Mutation (SNP) | VAF 15/166 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.745); catalogued as COSV55237700; called by muse, mutect2
- CAPSL | c.608G>A p.R203K | Missense Mutation (SNP) | VAF 37/145 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV68439014; called by muse, varscan2
- CAPSL | c.295G>A p.E99K | Missense Mutation (SNP) | VAF 37/169 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101274332; called by muse, mutect2, varscan2
- CAPZA3 | c.76G>A p.E26K | Missense Mutation (SNP) | VAF 44/113 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as rs377290206, COSV56856804; called by muse, mutect2, varscan2
- CARD11 | c.3275G>A p.R1092Q | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.164); catalogued as rs758055212, COSV101211085; called by muse, mutect2, varscan2
- CARD11 | c.3001T>C p.F1001L | Missense Mutation (SNP) | VAF 49/189 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.194); catalogued as COSV101211086; called by muse, mutect2, varscan2
- CARD11 | c.1055C>T p.S352L | Missense Mutation (SNP) | VAF 49/206 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.087); catalogued as COSV101211087, COSV67799608; called by muse, mutect2, varscan2
- CARD11 | c.745C>T p.Q249* | Nonsense Mutation (SNP) | VAF 77/218 reads (35%) | catalogued as COSV101211088, COSV67803181; called by muse, mutect2, varscan2
- CARD11 | c.376G>A p.G126S | Missense Mutation (SNP) | VAF 30/120 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100712301; called by muse, varscan2
- CARD6 | c.967G>A p.G323R | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as COSV99620467, COSV99621456; called by muse, varscan2
- CARD6 | c.993G>A p.M331I | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV99621459; called by muse, varscan2
- CARD6 | c.2107C>T p.Q703* | Nonsense Mutation (SNP) | VAF 115/428 reads (27%) | catalogued as COSV54564046, COSV99621462; called by muse, mutect2, varscan2
- CARMIL1 | c.3617C>T p.S1206L | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0); catalogued as rs868768530, COSV61520295; called by muse, mutect2
- CASK | c.625C>T p.L209F | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as COSV100587890; called by muse, mutect2
- CASP2 | c.364C>T p.L122F | Missense Mutation (SNP) | VAF 20/292 reads (7%) | SIFT tolerated (0.39); PolyPhen benign (0.011); catalogued as COSV100131334, COSV60081659; called by muse, mutect2
- CASS4 | c.1400G>A p.R467K | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64385700; called by muse, mutect2, varscan2
- CAST | c.1699C>T p.L567F (on ENST00000341926; = p.L650F on NM_001750.7 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 63/198 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV57085812, COSV99701362; called by muse, mutect2, varscan2
- CATIP | c.661G>A p.D221N | Missense Mutation (SNP) | VAF 56/160 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs1029958635, COSV99179674; called by muse, mutect2, varscan2
- CATSPERB | c.2861C>T p.S954F | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT tolerated (0.71); PolyPhen benign (0.022); catalogued as COSV99831938; called by muse, mutect2, varscan2
- CATSPERD | c.707C>T p.S236F | Missense Mutation (SNP) | VAF 125/403 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.769); catalogued as COSV101062868; called by muse, mutect2, varscan2
- CATSPERD | c.2075C>T p.S692L | Missense Mutation (SNP) | VAF 32/101 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.452); catalogued as rs774298301, COSV58465150, COSV58466015; called by muse, mutect2, varscan2
- CAV3 | c.287C>T p.S96F | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as rs730880421, COSV57478587; called by muse, mutect2, varscan2
- CBL | c.256G>A p.D86N | Missense Mutation (SNP) | VAF 36/86 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99877313; called by muse, mutect2, varscan2
- CBL | c.1166A>C p.K389T | Missense Mutation (SNP) | VAF 37/74 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99877316; called by muse, mutect2, varscan2
- CBLB | c.1016C>T p.P339L | Missense Mutation (SNP) | VAF 35/111 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99914657; called by muse, mutect2, varscan2
- CBLB | c.1015C>A p.P339T | Missense Mutation (SNP) | VAF 35/111 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99914659; called by muse, mutect2, varscan2
- CBLN2 | c.667C>T p.P223S | Missense Mutation (SNP) | VAF 53/143 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as rs868142587, COSV54050532; called by muse, mutect2, varscan2
- CBX2 | c.1162C>T p.P388S | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV99491073; called by muse, mutect2, varscan2
- CBX6 | c.785C>T p.A262V | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV53320353; called by muse, mutect2, varscan2
- CBY2 | c.433C>T p.P145S | Missense Mutation (SNP) | VAF 63/183 reads (34%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs368820329; called by muse, mutect2, varscan2
- CCBE1 | c.736C>T p.P246S | Missense Mutation (SNP) | VAF 58/149 reads (39%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.492); catalogued as rs868101186, COSV67949619; called by muse, mutect2, varscan2
- CCBE1 | c.624G>A p.M208I | Missense Mutation (SNP) | VAF 37/95 reads (39%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs1251835553, COSV101232881; called by muse, mutect2, varscan2
- CCDC102B | c.751G>A p.E251K | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.067); catalogued as COSV60140581; called by muse, mutect2, varscan2
- CCDC114 | c.1135C>T p.Q379* | Nonsense Mutation (SNP) | VAF 26/118 reads (22%) | catalogued as COSV100197197; called by muse, mutect2, varscan2
- CCDC114 | c.1126G>A p.A376T | Missense Mutation (SNP) | VAF 43/119 reads (36%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as COSV100197199; called by muse, mutect2, varscan2
- CCDC141 | c.3136G>A p.E1046K | Missense Mutation (SNP) | VAF 29/128 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.299); catalogued as COSV55373805; called by muse, mutect2, varscan2
- CCDC146 | c.1234G>A p.E412K | Missense Mutation (SNP) | VAF 108/314 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53546971; called by muse, mutect2, varscan2
- CCDC146 | c.1287G>A p.M429I | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV99593288; called by muse, mutect2, varscan2
- CCDC146 | c.1288G>A p.E430K | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.319); catalogued as COSV99593292; called by muse, mutect2, varscan2
- CCDC151 | c.892G>A p.E298K | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); catalogued as COSV62697245; called by muse, mutect2, varscan2
- CCDC151 | c.367G>A p.G123R | Missense Mutation (SNP) | VAF 61/181 reads (34%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV99371772, COSV99372052; called by muse, mutect2, varscan2
- CCDC158 | c.3157+1G>A p.X1053_splice | Splice Site (SNP) | VAF 35/104 reads (34%) | catalogued as COSV101187429; called by muse, mutect2, varscan2
- CCDC170 | c.1211T>G p.L404R | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV99499007; called by mutect2, varscan2
- CCDC178 | c.425C>T p.P142L | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.269); catalogued as COSV100287469; called by muse, mutect2, varscan2
- CCDC18 | c.121G>A p.E41K | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.202); catalogued as COSV100160078; called by muse, mutect2, varscan2
- CCDC181 | c.710G>A p.G237E | Missense Mutation (SNP) | VAF 111/246 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100890412; called by muse, mutect2, varscan2
- CCDC27 | c.496T>G p.W166G | Missense Mutation (SNP) | VAF 135/525 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.476); catalogued as COSV99623061; called by muse, mutect2, varscan2
- CCDC27 | c.1024G>A p.G342S | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.35); PolyPhen benign (0.023); catalogued as COSV99623064; called by muse, mutect2
- CCDC32 | c.277C>T p.Q93* | Nonsense Mutation (SNP) | VAF 21/78 reads (27%) | catalogued as COSV100786028; called by muse, mutect2, varscan2
- CCDC33 | c.206A>T p.K69M | Missense Mutation (SNP) | VAF 44/108 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.264); catalogued as COSV100351985; called by muse, mutect2, varscan2
- CCDC33 | c.2160G>A p.M720I | Missense Mutation (SNP) | VAF 50/191 reads (26%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as COSV51435240; called by muse, varscan2
- CCDC40 | c.2743C>T p.Q915* | Nonsense Mutation (SNP) | VAF 27/174 reads (16%) | catalogued as COSV66476748; called by muse, varscan2
- CCDC42 | c.189G>A p.K63= | Splice Region (SNP) | VAF 31/84 reads (37%) | catalogued as COSV99549955; called by muse, mutect2, varscan2
- CCDC47 | c.893C>T p.S298F | Missense Mutation (SNP) | VAF 15/140 reads (11%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.983); catalogued as COSV56723614; called by muse, mutect2, varscan2
- CCDC50 | c.500C>A p.P167H | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.545); catalogued as COSV101165376, COSV66669817; called by muse, mutect2, varscan2
- CCDC60 | c.782C>T p.S261L | Missense Mutation (SNP) | VAF 105/295 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs772386912, COSV59540809; called by muse, varscan2
- CCDC68 | c.623G>A p.R208K | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61604050; called by muse, mutect2, varscan2
- CCDC7 | c.2329G>A p.G777R | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.258); catalogued as rs758979320, COSV100179453; called by muse, mutect2, varscan2
- CCDC70 | c.333G>A p.W111* | Nonsense Mutation (SNP) | VAF 83/269 reads (31%) | catalogued as COSV54430494; called by muse, mutect2, varscan2
7,723 further variants in this file (4,706 protein-altering or splice-affecting, 2,798 silent, 219 other) are not listed here.
